Somatic mutation profile of tumor specimen C3L-00095-01 (aliquot CPT0001660005) from CPTAC case C3L-00095, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G2; Age at diagnosis: 62.6 years (22,863 days).
Specimen C3L-00095-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e02a5e32-9a66-415c-b79c-4ef30f360ff5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00095-31 (Blood Derived Normal), aliquot CPT0003910002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/06246c85-658a-4f5b-9c29-28a86e2bef7b

The open-access MAF lists 809 somatic variants for this specimen: 537 protein-altering or splice-affecting, 177 silent, 95 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 464, Silent 177, Intron 51, Nonsense Mutation 35, Splice Site 17, RNA 15, Frame Shift Del 11, 5'UTR 10, 3'UTR 9, Splice Region 9, 5'Flank 5, 3'Flank 5.

Variants (750 of 809; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYO7A | c.635G>A p.R212H | Missense Mutation (SNP) | VAF 16/223 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs28934610, CM950827, COSV68685383; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- TP53 | c.467G>C p.R156P | Missense Mutation (SNP) | VAF 20/240 reads (8%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.876); catalogued as rs371524413, CM984589, COSV52698013, COSV52700732, COSV52710835, COSV52891661; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2
- ACP6 | c.349-1G>A p.X117_splice | Splice Site (SNP) | VAF 12/188 reads (6%) | catalogued as COSV65076887; called by muse, mutect2
- ADGRL2 | c.2617C>A p.R873S (on ENST00000370717 / NM_001366005.1; = p.R860S on NM_012302.4) | Missense Mutation (SNP) | VAF 30/342 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV54696530; called by muse, mutect2
- ALOX5 | c.162C>A p.Y54* | Nonsense Mutation (SNP) | VAF 20/282 reads (7%) | catalogued as COSV100979976; called by muse, mutect2
- ANK2 | c.6658G>C p.E2220Q | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.623); catalogued as COSV100000228; called by muse, mutect2
- APCDD1 | c.1267G>C p.E423Q | Missense Mutation (SNP) | VAF 30/342 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV100789995; called by muse, mutect2
- ARID1B | c.3838G>T p.E1280* | Nonsense Mutation (SNP) | VAF 27/359 reads (8%) | catalogued as rs752398721; called by muse, mutect2
- ARPIN | c.211C>T p.R71C | Missense Mutation (SNP) | VAF 27/223 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs374275505; called by muse, mutect2, varscan2
- ASTN1 | c.2605T>C p.S869P | Missense Mutation (SNP) | VAF 17/236 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.623); catalogued as COSV56061214; called by muse, mutect2
- ASXL2 | c.3769G>C p.D1257H | Missense Mutation (SNP) | VAF 16/217 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55470381; called by muse, mutect2
- ATP1A2 | c.674G>T p.R225L | Missense Mutation (SNP) | VAF 28/324 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.373); catalogued as COSV63402865; called by muse, mutect2
- ATP8B2 | c.320C>A p.S107Y (on ENST00000672630; = p.S74Y on NM_001005855.2) | Missense Mutation (SNP) | VAF 17/232 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59246513; called by muse, mutect2
- ATR | c.5074G>A p.V1692I | Missense Mutation (SNP) | VAF 21/340 reads (6%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); catalogued as COSV63390639; called by muse, mutect2
- BIN1 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 25/378 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as rs764377144; ClinVar: uncertain significance; called by muse, mutect2
- BTK | c.1044G>T p.E348D | Missense Mutation (SNP) | VAF 35/299 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV100437735; called by muse, mutect2, varscan2
- CABIN1 | c.5914G>T p.A1972S | Missense Mutation (SNP) | VAF 23/338 reads (7%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0.025); catalogued as COSV99572621; called by muse, mutect2
- CACNA1I | c.6034G>A p.G2012R | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs1273247548; called by muse, mutect2
- CAPN13 | c.794G>T p.W265L | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as COSV54428457, COSV54428528; called by muse, mutect2, varscan2
- CAPN15 | c.2699A>T p.H900L | Missense Mutation (SNP) | VAF 25/308 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99562736; called by muse, mutect2
- CASQ1 | c.129C>A p.Y43* | Nonsense Mutation (SNP) | VAF 40/406 reads (10%) | catalogued as COSV63624607; called by muse, mutect2, varscan2
- CBY2 | c.227C>A p.A76D | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.711); catalogued as COSV60120080; called by muse, mutect2
- CDH9 | c.1555C>G p.R519G | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as COSV50446689; called by muse, mutect2
- CEP192 | c.5322G>T p.W1774C | Missense Mutation (SNP) | VAF 13/147 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1483750182; called by muse, mutect2
- CHRNA4 | c.910C>G p.P304A | Missense Mutation (SNP) | VAF 68/843 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1254356160; called by muse, mutect2
- CLK2 | c.436G>A p.D146N (on ENST00000368361 / NM_001294339.2; = p.D145N on NM_003993.4) | Missense Mutation (SNP) | VAF 23/203 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.621); catalogued as rs774051104; called by muse, mutect2, varscan2
- CNGA4 | c.1670G>C p.G557A | Missense Mutation (SNP) | VAF 17/220 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.023); catalogued as COSV66007491; called by muse, mutect2
- CNTNAP4 | c.2755G>T p.G919C | Missense Mutation (SNP) | VAF 11/162 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV100270346; called by muse, mutect2
- CNTNAP4 | c.3075C>A p.S1025R | Missense Mutation (SNP) | VAF 19/219 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.92); catalogued as COSV100271716; called by muse, mutect2
- COL11A1 | c.1640G>T p.G547V | Missense Mutation (SNP) | VAF 35/273 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62180749; called by muse, mutect2, varscan2
- COL24A1 | c.4554C>G p.F1518L | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.145); catalogued as COSV65306538; called by muse, mutect2, varscan2
- CPN1 | c.1156A>G p.T386A | Missense Mutation (SNP) | VAF 34/451 reads (8%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as rs772671251; called by muse, mutect2
- CSMD3 | c.6157C>A p.P2053T (on ENST00000297405 / NM_001363185.1; = p.P1949T on NM_052900.3) | Missense Mutation (SNP) | VAF 49/319 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.464); catalogued as COSV52219210, COSV99831986; called by muse, mutect2, varscan2
- CSMD3 | c.1249C>A p.P417T | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99832791; called by muse, mutect2
- CST4 | c.197G>C p.R66P | Missense Mutation (SNP) | VAF 16/182 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54150608, COSV99463081; called by muse, mutect2
- CYP11B2 | c.1040C>T p.A347V | Missense Mutation (SNP) | VAF 26/439 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.903); catalogued as COSV100010454; called by muse, mutect2
- CYP17A1 | c.191A>G p.Y64C | Missense Mutation (SNP) | VAF 12/279 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as CM931231; called by muse, mutect2
- DAXX | c.10G>T p.A4S | Missense Mutation (SNP) | VAF 9/107 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.168); catalogued as COSV56470361; called by muse, mutect2
- DCDC1 | c.5119A>T p.R1707* (on ENST00000597505 / NM_001367979.1; = p.R814* on NM_020869.3) | Nonsense Mutation (SNP) | VAF 16/246 reads (7%) | catalogued as COSV57998226; called by muse, mutect2
- DNAH1 | c.3265G>A p.E1089K | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.059); catalogued as rs752415237; called by muse, mutect2, varscan2
- DPYD | c.827A>T p.Y276F | Missense Mutation (SNP) | VAF 18/263 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs1313976976, COSV64616002; called by muse, mutect2
- EGFL8 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 18/224 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.681); catalogued as rs1561837018; called by muse, mutect2
- ERICH3 | c.2020G>T p.E674* | Nonsense Mutation (SNP) | VAF 20/285 reads (7%) | catalogued as rs1274251958, COSV58605055; called by muse, mutect2
- EXTL1 | c.827C>A p.S276Y | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV65337031; called by muse, mutect2
- FAM181B | c.737C>T p.S246L | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.244); catalogued as rs1213670452; called by muse, mutect2
- FAM47A | c.656del p.P219Rfs*47 | Frame Shift Del (DEL) | VAF 9/85 reads (11%) | catalogued as COSV60496289; called by pindel, varscan2
- FBXO4 | c.955G>C p.G319R | Missense Mutation (SNP) | VAF 17/196 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55851994; called by muse, mutect2
- FEZF1 | c.368G>A p.C123Y | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs1172830506; called by muse, mutect2, varscan2
- GABRA4 | c.997G>T p.A333S | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99973876, COSV99974089; called by muse, mutect2
- GLI2 | c.3011G>T p.R1004L (on ENST00000361492 / NM_001374353.1; = p.R1021L on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/177 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.268); catalogued as COSV58053376; called by muse, mutect2, varscan2
- GPR37 | c.872A>G p.Y291C | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.99); catalogued as COSV100391193; called by muse, mutect2
- GRID2 | c.2098G>T p.E700* | Nonsense Mutation (SNP) | VAF 22/202 reads (11%) | catalogued as COSV56253148; called by muse, mutect2, varscan2
- GRIK4 | c.441C>A p.S147R | Missense Mutation (SNP) | VAF 19/262 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70800953; called by muse, mutect2
- GRIK4 | c.1411G>T p.G471C | Missense Mutation (SNP) | VAF 33/400 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV70803655; called by muse, mutect2
- HAVCR2 | c.635G>T p.G212V | Missense Mutation (SNP) | VAF 26/249 reads (10%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.451); catalogued as COSV100324726; called by muse, mutect2, varscan2
- HECW1 | c.460+1G>T p.X154_splice | Splice Site (SNP) | VAF 17/195 reads (9%) | catalogued as COSV67823008; called by muse, mutect2
- HGF | c.724C>T p.R242W | Missense Mutation (SNP) | VAF 30/326 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs202185530, COSV99735880, COSV99737070; called by muse, mutect2
- HINFP | c.143G>T p.G48V | Missense Mutation (SNP) | VAF 20/178 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV99052860; called by muse, mutect2, varscan2
- IL1RN | c.187C>A p.P63T (on ENST00000409930 / NM_173842.3; = p.P45T on NM_000577.5) | Missense Mutation (SNP) | VAF 26/328 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs746404239; called by muse, mutect2
- KATNIP | c.1463G>T p.G488V | Missense Mutation (SNP) | VAF 12/232 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55190839; called by muse, mutect2
- KCNA4 | c.82del p.R28Gfs*81 | Frame Shift Del (DEL) | VAF 6/54 reads (11%) | catalogued as COSV100069040; called by mutect2, pindel
- KCNK9 | c.842C>A p.P281H | Missense Mutation (SNP) | VAF 14/241 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs1464626379; called by muse, mutect2
- KDM5C | c.1367G>T p.S456I | Missense Mutation (SNP) | VAF 18/155 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.147); catalogued as COSV64770391; called by muse, mutect2, varscan2
- KIAA1217 | c.239G>C p.G80A | Missense Mutation (SNP) | VAF 18/188 reads (10%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.487); catalogued as rs1486516049; called by muse, mutect2
- KIF2B | c.1804C>T p.P602S | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV52128279; called by muse, mutect2
- KLF5 | c.1250C>T p.S417L | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV66614473; called by muse, mutect2
- KLF5 | c.1252G>A p.D418N | Missense Mutation (SNP) | VAF 12/179 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV66614445, COSV66614565; called by muse, mutect2
- LAMC3 | c.931C>G p.R311G | Missense Mutation (SNP) | VAF 38/339 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV63092404, COSV63095855; called by muse, mutect2, varscan2
- LMAN2 | c.662G>T p.R221L | Missense Mutation (SNP) | VAF 22/180 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.146); catalogued as COSV57424489; called by muse, mutect2, varscan2
- LRRC7 | c.3152G>T p.S1051I (on ENST00000651989 / NM_001370785.2; = p.S1018I on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/280 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as COSV50459458; called by muse, mutect2
- LRRTM3 | c.116G>T p.R39M | Missense Mutation (SNP) | VAF 14/228 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63665467, COSV63666233; called by muse, mutect2
- MAP10 | c.313C>G p.Q105E | Missense Mutation (SNP) | VAF 24/391 reads (6%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.075); catalogued as COSV69363148; called by muse, mutect2
- MAP3K19 | c.2729C>A p.A910E | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100209004; called by muse, mutect2
- MAP4K4 | c.2492A>T p.K831M (on ENST00000347699 / NM_001242559.2; = p.K749M on NM_004834.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/239 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.994); catalogued as rs1333198693; called by muse, mutect2
- MAPT | c.1175A>T p.H392L (on ENST00000262410 / NM_001377265.1; = p.H317L on NM_016835.4) | Missense Mutation (SNP) | VAF 29/409 reads (7%) | SIFT tolerated (0.66); PolyPhen benign (0.031); catalogued as COSV52245637; called by muse, mutect2
- MKRN3 | c.998C>G p.S333C | Missense Mutation (SNP) | VAF 22/286 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs1420266188; called by muse, mutect2
- MRC1 | c.3817A>T p.I1273F | Missense Mutation (SNP) | VAF 18/550 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs1275127706; called by muse, mutect2
- MS4A13 | c.454C>A p.P152T | Missense Mutation (SNP) | VAF 9/163 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1419971153; called by muse, mutect2
- MSI2 | c.643G>T p.G215W | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV52362499; called by muse, mutect2, varscan2
- MSLN | c.814C>T p.R272W | Missense Mutation (SNP) | VAF 21/214 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs200634525; called by muse, mutect2
- MUC16 | c.42866C>A p.S14289* | Nonsense Mutation (SNP) | VAF 12/179 reads (7%) | catalogued as COSV101109889; called by muse, mutect2
- MYH8 | c.4030G>T p.D1344Y | Missense Mutation (SNP) | VAF 40/419 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV67964011; called by muse, mutect2
- MYH8 | c.98C>A p.P33Q | Missense Mutation (SNP) | VAF 44/488 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.604); catalogued as COSV67963691; called by muse, mutect2
- MYO5B | c.1684G>T p.D562Y | Missense Mutation (SNP) | VAF 36/452 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as COSV53211359; called by muse, mutect2
- NDUFA10 | c.296G>T p.G99V | Missense Mutation (SNP) | VAF 26/344 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as CM120094, COSV53152959; called by muse, mutect2
- NEGR1 | c.1032C>A p.S344R | Missense Mutation (SNP) | VAF 15/215 reads (7%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.46); catalogued as COSV100167000; called by muse, mutect2
- NHLRC1 | c.313C>A p.R105S | Missense Mutation (SNP) | VAF 14/210 reads (7%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as rs909097062, COSV100513595; called by muse, mutect2
- NPIPB15 | c.196G>A p.G66R | Missense Mutation (SNP) | VAF 25/624 reads (4%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.771); catalogued as COSV70437870; called by muse, mutect2
- OPRK1 | c.138C>G p.D46E | Missense Mutation (SNP) | VAF 29/225 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV55569822, COSV99653542; called by muse, mutect2, varscan2
- OR2F2 | c.764C>A p.T255K | Missense Mutation (SNP) | VAF 31/202 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.373); catalogued as rs755050627; called by muse, mutect2, varscan2
- OR2L3 | c.257C>T p.S86F | Missense Mutation (SNP) | VAF 27/388 reads (7%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV63454651, COSV63456579; called by muse, mutect2
- OR4K5 | c.566G>T p.C189F | Missense Mutation (SNP) | VAF 30/320 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1221834647, COSV60003235; called by muse, mutect2
- OR56B1 | c.311C>G p.P104R | Missense Mutation (SNP) | VAF 23/227 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.563); catalogued as COSV100402738; called by muse, mutect2, varscan2
- OR5M10 | c.266A>C p.Q89P | Missense Mutation (SNP) | VAF 24/332 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.105); catalogued as rs778808882; called by muse, mutect2
- OR8A1 | c.539T>A p.I180N | Missense Mutation (SNP) | VAF 24/224 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.774); catalogued as rs1178562085; called by muse, mutect2, varscan2
- OTOP1 | c.439C>A p.L147M | Missense Mutation (SNP) | VAF 10/193 reads (5%) | SIFT tolerated (0.49); PolyPhen benign (0.191); catalogued as COSV56390265; called by muse, mutect2
- OTUD7B | c.1856A>G p.H619R | Missense Mutation (SNP) | VAF 24/374 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.347); catalogued as rs1553771491, COSV64915842; called by muse, mutect2
- PCARE | c.2239C>A p.L747M | Missense Mutation (SNP) | VAF 8/127 reads (6%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.794); catalogued as COSV59056385; called by muse, mutect2
- PCDH15 | c.2933T>A p.I978N | Missense Mutation (SNP) | VAF 16/233 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57278235; called by muse, mutect2
- PCDHB3 | c.195A>C p.Q65H | Missense Mutation (SNP) | VAF 7/109 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.042); catalogued as COSV50582246; called by muse, mutect2
- PCDHGA12 | c.185G>T p.R62L | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.178); catalogued as COSV52754675; called by muse, mutect2, varscan2
- PHF21B | c.937T>A p.Y313N | Missense Mutation (SNP) | VAF 18/194 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.085); catalogued as COSV57556470; called by muse, mutect2
- PIF1 | c.921G>C p.E307D | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51423760; called by muse, mutect2
- PLD5 | c.466C>G p.L156V (on ENST00000442594; = p.L94V on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/268 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV59151290; called by muse, mutect2, varscan2
- PLEKHA4 | c.523G>A p.G175S | Missense Mutation (SNP) | VAF 40/219 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs779348368; called by muse, mutect2, varscan2
- PLEKHM1 | c.911G>T p.R304L | Missense Mutation (SNP) | VAF 29/410 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.02); catalogued as COSV101378938; called by muse, mutect2
- PLP1 | c.649G>A p.G217S | Missense Mutation (SNP) | VAF 47/290 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.934); catalogued as CM952022; called by muse, mutect2, varscan2
- PLXNA2 | c.5441A>G p.Y1814C | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1229255443; called by muse, mutect2
- PPP1R3A | c.1063G>T p.G355W | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as COSV52895114; called by muse, mutect2, varscan2
- PRSS1 | c.201-3C>T | Splice Region (SNP) | VAF 49/451 reads (11%) | catalogued as rs1404070944, COSV100298032; called by muse, mutect2, varscan2
- PSAP | c.1540-1G>T p.X514_splice | Splice Site (SNP) | VAF 29/386 reads (8%) | catalogued as rs113435418; called by muse, mutect2
- PTPRB | c.2872G>A p.V958I | Missense Mutation (SNP) | VAF 38/593 reads (6%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as rs527418611, COSV54241912; called by muse, mutect2
- RAG2 | c.1234G>A p.E412K | Missense Mutation (SNP) | VAF 37/375 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as COSV57558655; called by muse, mutect2
- RBL1 | c.2115G>T p.M705I | Missense Mutation (SNP) | VAF 10/188 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as rs868864393; called by muse, mutect2
- RBM10 | c.308G>T p.R103L | Missense Mutation (SNP) | VAF 26/224 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.357); catalogued as COSV61308776; called by muse, varscan2
- RCAN1 | c.110C>T p.S37L | Missense Mutation (SNP) | VAF 16/220 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV58249993, COSV58250681; called by muse, mutect2
- REM2 | c.893del p.G298Afs*152 | Frame Shift Del (DEL) | VAF 11/108 reads (10%) | catalogued as COSV57465668; called by mutect2, pindel
- REPIN1 | c.647C>T p.P216L | Missense Mutation (SNP) | VAF 18/181 reads (10%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.996); catalogued as rs1203669495; called by muse, mutect2, varscan2
- RHBDF1 | c.1385G>T p.G462V | Missense Mutation (SNP) | VAF 16/259 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51953353; called by muse, mutect2
- RNASE9 | c.82G>T p.E28* | Nonsense Mutation (SNP) | VAF 9/180 reads (5%) | catalogued as COSV58880314; called by muse, mutect2
- RNF213 | c.13425G>A p.M4475I | Missense Mutation (SNP) | VAF 34/354 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs1377050706; called by muse, mutect2
- ROM1 | c.311T>C p.L104P | Missense Mutation (SNP) | VAF 12/182 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as rs971348631; called by muse, mutect2
- RPL10L | c.457C>G p.R153G | Missense Mutation (SNP) | VAF 36/269 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.44); catalogued as rs199562673, COSV53561059; called by muse, mutect2, varscan2
- RYR2 | c.3244G>T p.G1082W | Missense Mutation (SNP) | VAF 16/186 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.24); catalogued as COSV63679863; called by muse, mutect2
- RYR2 | c.6793-1G>C p.X2265_splice | Splice Site (SNP) | VAF 20/367 reads (5%) | catalogued as COSV63704246; called by muse, mutect2
- SAMD9 | c.3436G>T p.V1146F | Missense Mutation (SNP) | VAF 44/385 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as rs746851927; called by muse, mutect2, varscan2
- SATL1 | c.229C>G p.P77A (on ENST00000395409; = p.P264A on NM_001012980.2) | Missense Mutation (SNP) | VAF 40/250 reads (16%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.681); catalogued as COSV60576422; called by muse, mutect2, varscan2
- SCN1A | c.4339G>C p.V1447L (on ENST00000303395 / NM_001202435.3; = p.V1436L on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.102); catalogued as rs1559119642; ClinVar: uncertain significance; called by muse, mutect2
- SEMA6B | c.419C>A p.T140K | Missense Mutation (SNP) | VAF 13/172 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.941); catalogued as rs770360894, COSV56703553; called by muse, mutect2
- SLC2A10 | c.212G>T p.C71F | Missense Mutation (SNP) | VAF 30/224 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.213); catalogued as rs377305511; ClinVar: uncertain significance; called by muse, varscan2
- SLC6A2 | c.1241C>G p.A414G | Missense Mutation (SNP) | VAF 34/388 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.175); catalogued as COSV54918713; called by muse, mutect2
- SLITRK3 | c.2354C>A p.P785Q | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.085); catalogued as COSV53852040; called by muse, mutect2
- SLITRK4 | c.1838G>T p.G613V | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.909); catalogued as COSV62022272; called by muse, mutect2, varscan2
- SLITRK6 | c.886A>T p.M296L | Missense Mutation (SNP) | VAF 12/200 reads (6%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV68392070; called by muse, mutect2
- SMARCA1 | c.524C>G p.P175R | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64411554; called by muse, mutect2, varscan2
- SMOC2 | c.1222G>A p.E408K (on ENST00000356284 / NM_001166412.2; = p.E419K on NM_022138.3) | Missense Mutation (SNP) | VAF 22/218 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1041903275, COSV100635303, COSV62434875; called by muse, mutect2, varscan2
- SMPD4 | c.1373G>A p.S458N (on ENST00000409031 / NM_017951.4; = p.S429N on NM_017751.4) | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs1337121103; called by muse, mutect2
- SPAST | c.782C>T p.S261L | Missense Mutation (SNP) | VAF 32/375 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.212); catalogued as rs768241184, CM000430, CM107565, COSV59512678, COSV59514377; called by muse, mutect2
- SPATA16 | c.337C>A p.P113T | Missense Mutation (SNP) | VAF 38/674 reads (6%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.91); catalogued as COSV100650911; called by muse, mutect2
- SPEF2 | c.4605G>T p.W1535C | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.088); catalogued as COSV57431887; called by muse, mutect2, varscan2
- SRSF8 | c.572G>C p.S191T | Missense Mutation (SNP) | VAF 28/548 reads (5%) | SIFT tolerated, low confidence (0.27); PolyPhen possibly damaging (0.636); catalogued as rs782429932, COSV101475804; called by muse, mutect2
- TBR1 | c.1945G>A p.E649K | Missense Mutation (SNP) | VAF 21/264 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.317); catalogued as COSV101271490; called by muse, mutect2
- TDRD5 | c.1846G>A p.G616S | Missense Mutation (SNP) | VAF 45/322 reads (14%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.521); catalogued as rs199784694; called by muse, mutect2, varscan2
- TENM4 | c.5836G>C p.E1946Q | Missense Mutation (SNP) | VAF 5/95 reads (5%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.986); catalogued as COSV53623121; called by muse, mutect2
- TNR | c.1897G>T p.G633C | Missense Mutation (SNP) | VAF 19/165 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54918718, COSV99691499; called by muse, mutect2, varscan2
- TPTE | c.115G>T p.E39* | Nonsense Mutation (SNP) | VAF 11/247 reads (4%) | catalogued as rs1398151563; called by muse, mutect2
- TRIM64B | c.335G>C p.G112A | Missense Mutation (SNP) | VAF 21/392 reads (5%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.874); catalogued as rs1325525219; called by muse, mutect2
- TRPA1 | c.1269G>T p.Q423H | Missense Mutation (SNP) | VAF 26/402 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.014); catalogued as COSV100084153, COSV51569164; called by muse, mutect2
- TUBA3C | c.840G>T p.K280N | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.155); catalogued as COSV67138970; called by muse, mutect2, varscan2
- UBE3C | c.763G>T p.G255C | Missense Mutation (SNP) | VAF 25/352 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.417); catalogued as rs1359195761; called by muse, mutect2
- UGT1A3 | c.851G>A p.R284K | Missense Mutation (SNP) | VAF 69/307 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs998716172; called by muse, mutect2, varscan2
- UGT2B10 | c.320C>A p.P107H | Missense Mutation (SNP) | VAF 13/217 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs765298425; called by muse, mutect2
- UPK2 | c.203G>T p.S68I | Missense Mutation (SNP) | VAF 22/175 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs146976408; called by muse, mutect2, varscan2
- USH2A | c.6806-1G>T p.X2269_splice | Splice Site (SNP) | VAF 21/346 reads (6%) | catalogued as COSV99048372; called by muse, mutect2
- VIM | c.809G>T p.R270L | Missense Mutation (SNP) | VAF 32/326 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV56406480; called by muse, mutect2
- VSTM2A | c.224G>T p.G75V | Missense Mutation (SNP) | VAF 12/149 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.447); catalogued as COSV56492418; called by muse, mutect2
- XIRP2 | c.9547G>A p.G3183R (on ENST00000628543; = p.G3358R on NM_152381.6) | Missense Mutation (SNP) | VAF 10/198 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54706607; called by muse, mutect2
- XKR5 | c.1150C>A p.P384T | Missense Mutation (SNP) | VAF 12/254 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0.038); catalogued as rs1001879021; called by muse, mutect2
- ZC3H18 | c.1921G>T p.A641S | Missense Mutation (SNP) | VAF 37/380 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.037); catalogued as rs1394006235; called by muse, mutect2, varscan2
- ZNF234 | c.2029G>T p.G677C | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.43); catalogued as rs773420098; called by muse, mutect2, varscan2
- ZNF250 | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 28/307 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1563879752, COSV52969800; called by muse, mutect2
- ZNF410 | c.542G>T p.R181L | Missense Mutation (SNP) | VAF 45/383 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.02); catalogued as COSV100206559, COSV57912686; called by muse, mutect2, varscan2
- ZNF438 | c.1572C>A p.D524E | Missense Mutation (SNP) | VAF 34/416 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.136); catalogued as rs778566927; called by muse, mutect2
- ZNF486 | c.1288G>A p.G430R | Missense Mutation (SNP) | VAF 28/350 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.25); catalogued as COSV100631305; called by muse, mutect2
- ZNF521 | c.857G>T p.C286F | Missense Mutation (SNP) | VAF 24/292 reads (8%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV64123681; called by muse, mutect2
- ZNF521 | c.856T>C p.C286R | Missense Mutation (SNP) | VAF 24/286 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1371535405; called by muse, mutect2
- ZNF536 | c.397C>A p.P133T | Missense Mutation (SNP) | VAF 30/546 reads (5%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.999); catalogued as COSV100834868; called by muse, mutect2
- ZNF831 | c.2872T>A p.W958R | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV100925923; called by muse, mutect2
- ZNF835 | c.976C>A p.R326S | Missense Mutation (SNP) | VAF 12/226 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV73379420; called by muse, mutect2
- ABCA13 | c.4195G>T p.D1399Y | Missense Mutation (SNP) | VAF 27/334 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.893); called by muse, mutect2
- ABTB2 | c.1525G>T p.A509S | Missense Mutation (SNP) | VAF 10/111 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.257); called by muse, mutect2
- ACSS3 | c.536C>G p.P179R | Missense Mutation (SNP) | VAF 14/139 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAMTS12 | c.2060C>T p.T687I | Missense Mutation (SNP) | VAF 8/141 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.05); called by muse, mutect2
- ADAMTS6 | c.2397G>T p.L799F | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADARB2 | c.1359G>C p.L453= | Splice Region (SNP) | VAF 8/89 reads (9%) | called by muse, mutect2
- ADCY7 | c.902T>G p.V301G | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ADGRE3 | c.1054G>T p.E352* | Nonsense Mutation (SNP) | VAF 31/241 reads (13%) | called by muse, mutect2, varscan2
- AEBP1 | c.1535C>A p.P512Q | Missense Mutation (SNP) | VAF 16/206 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- AGPAT4 | c.26C>G p.S9C | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); called by muse, mutect2
- AMH | c.421G>T p.E141* | Nonsense Mutation (SNP) | VAF 29/418 reads (7%) | called by muse, mutect2
- ANGPTL3 | c.88T>G p.S30A | Missense Mutation (SNP) | VAF 18/192 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.024); called by muse, mutect2
- ANK2 | c.4579G>T p.D1527Y | Missense Mutation (SNP) | VAF 23/304 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); called by muse, mutect2
- ANK2 | c.5455G>T p.A1819S | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0.003); called by muse, mutect2
- ANKFN1 | c.3500G>T p.W1167L (on ENST00000653862; = p.W1020L on NM_001365758.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/111 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- ANKS3 | c.157G>T p.E53* | Nonsense Mutation (SNP) | VAF 7/32 reads (22%) | called by muse, mutect2, varscan2
- ANXA7 | c.610G>C p.D204H (on ENST00000372919 / NM_001320880.2; = p.D182H on NM_001156.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/241 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- AP1M1 | c.1267C>T p.Q423* | Nonsense Mutation (SNP) | VAF 17/198 reads (9%) | called by muse, mutect2
- APBA2 | c.1270C>A p.Q424K | Missense Mutation (SNP) | VAF 38/328 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- ARHGAP22 | c.445G>T p.G149C | Missense Mutation (SNP) | VAF 10/185 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ARHGAP6 | c.1450G>T p.E484* | Nonsense Mutation (SNP) | VAF 12/62 reads (19%) | called by muse, mutect2, varscan2
- ARHGEF40 | c.610G>C p.E204Q | Missense Mutation (SNP) | VAF 14/244 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.04); called by muse, mutect2
- ASB10 | c.712G>C p.G238R (on ENST00000420175 / NM_001142459.2; = p.G223R on NM_080871.4) | Missense Mutation (SNP) | VAF 10/171 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ATP5F1A | c.793G>A p.D265N | Missense Mutation (SNP) | VAF 14/198 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.453); called by muse, mutect2
- ATXN7L1 | c.567G>T p.R189S | Missense Mutation (SNP) | VAF 14/192 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.031); called by muse, mutect2
- AXL | c.588del p.X196_splice | Splice Site (DEL) | VAF 24/173 reads (14%) | called by mutect2, pindel, varscan2
- B4GALNT2 | c.157G>T p.G53C | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.52); called by muse, mutect2
- BBOX1 | c.365T>A p.L122Q | Missense Mutation (SNP) | VAF 19/211 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- BCAS1 | c.1406C>A p.S469Y | Missense Mutation (SNP) | VAF 16/221 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.878); called by muse, mutect2
- BCAS1 | c.464G>T p.G155V | Missense Mutation (SNP) | VAF 14/307 reads (5%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.755); called by muse, mutect2
- BCL9L | c.4223A>C p.Q1408P | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.72); called by muse, mutect2
- BEND2 | c.1522T>A p.Y508N | Missense Mutation (SNP) | VAF 17/212 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- BICD1 | c.1155G>T p.K385N | Missense Mutation (SNP) | VAF 9/158 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.781); called by muse, mutect2
- C19orf12 | c.120del p.K41Rfs*32 (on ENST00000392278 / NM_001031726.3; = p.K30Rfs*32 on NM_031448.6) | Frame Shift Del (DEL) | VAF 26/324 reads (8%) | called by mutect2, pindel
- C1orf94 | c.1382G>T p.W461L (on ENST00000488417 / NM_001134734.2; = p.W271L on NM_032884.5) | Missense Mutation (SNP) | VAF 12/151 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); called by muse, mutect2
- C2CD2L | c.1757C>T p.P586L | Missense Mutation (SNP) | VAF 36/431 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.028); called by muse, mutect2
- CABS1 | c.701T>A p.L234H | Missense Mutation (SNP) | VAF 14/234 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.912); called by muse, mutect2
- CACNA2D3 | c.599T>C p.V200A | Missense Mutation (SNP) | VAF 12/215 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.38); called by muse, mutect2
- CAD | c.1006C>T p.H336Y | Missense Mutation (SNP) | VAF 14/161 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2
- CADM3 | c.153dup p.V52Sfs*13 (on ENST00000368125 / NM_001127173.3; = p.V86Sfs*13 on NM_021189.5) | Frame Shift Ins (INS) | VAF 32/381 reads (8%) | called by mutect2, pindel
- CALCR | c.434C>T p.A145V | Missense Mutation (SNP) | VAF 14/141 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- CAPN1 | c.394C>G p.H132D | Missense Mutation (SNP) | VAF 10/231 reads (4%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.939); called by muse, mutect2
- CAPN6 | c.1177G>C p.E393Q | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.588); called by muse, mutect2, varscan2
- CARM1 | c.558+2T>A p.X186_splice | Splice Site (SNP) | VAF 7/118 reads (6%) | called by muse, mutect2
- CARMIL2 | c.2589G>A p.R863= | Splice Region (SNP) | VAF 19/187 reads (10%) | called by muse, mutect2, varscan2
- CATIP | c.443G>C p.R148T | Missense Mutation (SNP) | VAF 26/165 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- CCDC168 | c.14146C>A p.P4716T | Missense Mutation (SNP) | VAF 15/268 reads (6%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.641); called by muse, mutect2
- CCDC68 | c.5C>T p.T2I | Missense Mutation (SNP) | VAF 16/251 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CCDC89 | c.958G>T p.A320S | Missense Mutation (SNP) | VAF 30/298 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.67); called by muse, mutect2
- CD79B | c.477T>A p.D159E | Missense Mutation (SNP) | VAF 46/632 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2
- CDCP2 | c.1082C>A p.T361N | Missense Mutation (SNP) | VAF 27/230 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.744); called by mutect2, varscan2
- CDH1 | c.1504G>T p.G502C | Missense Mutation (SNP) | VAF 26/350 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CDH20 | c.137T>A p.L46H | Missense Mutation (SNP) | VAF 43/416 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDH20 | c.2294C>A p.S765* | Nonsense Mutation (SNP) | VAF 16/226 reads (7%) | called by muse, mutect2
- CDHR1 | c.647G>T p.G216V | Missense Mutation (SNP) | VAF 33/380 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CDK8 | c.1183C>G p.H395D | Missense Mutation (SNP) | VAF 22/308 reads (7%) | SIFT tolerated (0.65); PolyPhen benign (0.035); called by muse, mutect2
- CERS3 | c.1066G>C p.A356P | Missense Mutation (SNP) | VAF 11/234 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0.094); called by muse, mutect2
- CETP | c.445G>A p.D149N | Missense Mutation (SNP) | VAF 28/420 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.104); called by muse, mutect2
- CFAP70 | c.1519G>A p.A507T | Missense Mutation (SNP) | VAF 18/222 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); called by muse, mutect2
- CHRDL1 | c.579C>A p.N193K (on ENST00000372045; = p.N199K on NM_145234.4) | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CHSY1 | c.1859A>T p.Q620L | Missense Mutation (SNP) | VAF 27/280 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.098); called by muse, mutect2
- CLDN14 | c.209T>A p.L70Q | Missense Mutation (SNP) | VAF 48/515 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.175); called by muse, mutect2
- CLUL1 | c.887T>C p.M296T | Missense Mutation (SNP) | VAF 20/205 reads (10%) | SIFT tolerated (0.63); PolyPhen benign (0.003); called by muse, mutect2
- COA8 | c.537G>T p.R179S | Missense Mutation (SNP) | VAF 35/270 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- COL11A1 | c.2518C>G p.P840A | Missense Mutation (SNP) | VAF 15/216 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2
- COL16A1 | c.4207C>T p.P1403S | Missense Mutation (SNP) | VAF 22/250 reads (9%) | SIFT tolerated (0.57); PolyPhen benign (0.031); called by muse, mutect2
- COL1A1 | c.2828C>T p.A943V | Missense Mutation (SNP) | VAF 46/610 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.058); called by muse, mutect2
- COL3A1 | c.4054G>A p.V1352M | Missense Mutation (SNP) | VAF 18/283 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); called by muse, mutect2
- COL4A1 | c.2968+1G>T p.X990_splice | Splice Site (SNP) | VAF 26/332 reads (8%) | called by muse, mutect2
- COL6A3 | c.9271T>C p.S3091P | Missense Mutation (SNP) | VAF 29/466 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.969); called by muse, mutect2
- COL6A6 | c.3937C>A p.L1313I | Missense Mutation (SNP) | VAF 12/135 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- CPT1C | c.2350T>G p.C784G | Missense Mutation (SNP) | VAF 24/167 reads (14%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- CRACD | c.1686G>C p.K562N | Missense Mutation (SNP) | VAF 18/157 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- CREB5 | c.854C>A p.P285Q (on ENST00000357727 / NM_182898.4; = p.P278Q on NM_004904.3) | Missense Mutation (SNP) | VAF 44/547 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.165); called by muse, mutect2
- CRISP1 | c.595C>A p.P199T | Missense Mutation (SNP) | VAF 22/157 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CRYBG2 | c.2101G>T p.D701Y | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- CSF2RB | c.1102A>G p.I368V | Missense Mutation (SNP) | VAF 18/272 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.067); called by muse, mutect2
- CSMD2 | c.8949G>T p.M2983I | Missense Mutation (SNP) | VAF 20/254 reads (8%) | SIFT tolerated (0.61); PolyPhen benign (0.001); called by muse, mutect2
- CTNND2 | c.2069A>T p.H690L | Missense Mutation (SNP) | VAF 17/158 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- CYP2R1 | c.1033G>T p.G345C | Missense Mutation (SNP) | VAF 16/184 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CYP46A1 | c.693+6G>A | Splice Region (SNP) | VAF 15/117 reads (13%) | called by muse, mutect2, varscan2
- CYP4F3 | c.576T>G p.F192L | Missense Mutation (SNP) | VAF 18/264 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.521); called by muse, mutect2
- DCAF12L2 | c.700C>A p.H234N | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- DCTN3 | c.234A>G p.I78M | Missense Mutation (SNP) | VAF 16/145 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DDC | c.200G>T p.G67V | Missense Mutation (SNP) | VAF 40/490 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DGKG | c.472G>T p.V158L | Missense Mutation (SNP) | VAF 16/194 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.013); called by muse, mutect2
- DIAPH2 | c.1351G>T p.E451* | Nonsense Mutation (SNP) | VAF 10/71 reads (14%) | called by muse, varscan2
- DISP3 | c.908G>T p.R303L | Missense Mutation (SNP) | VAF 9/130 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.698); called by muse, mutect2
- DMGDH | c.1006G>C p.E336Q | Missense Mutation (SNP) | VAF 32/379 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.089); called by muse, mutect2
- DMXL1 | c.7340G>T p.R2447I | Missense Mutation (SNP) | VAF 45/332 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- DNTT | c.783G>T p.K261N | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2
- DOCK1 | c.314A>T p.Q105L | Missense Mutation (SNP) | VAF 16/206 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2
- DOCK2 | c.1448A>G p.Q483R | Missense Mutation (SNP) | VAF 13/222 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2
- DOCK6 | c.4021+1G>T p.X1341_splice | Splice Site (SNP) | VAF 10/126 reads (8%) | called by muse, mutect2
- DPEP3 | c.1318C>A p.P440T | Missense Mutation (SNP) | VAF 17/298 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.001); called by muse, mutect2
- DPP10 | c.902G>C p.G301A | Missense Mutation (SNP) | VAF 20/246 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2
- DSG2 | c.1660G>T p.V554L | Missense Mutation (SNP) | VAF 34/500 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.012); called by muse, mutect2
- DYNC1I1 | c.188T>A p.L63Q | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ECPAS | c.4111-1G>T p.X1371_splice | Splice Site (SNP) | VAF 10/137 reads (7%) | called by muse, mutect2
- EDA2R | c.751C>A p.P251T | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.441); called by muse, mutect2, varscan2
- EIF4G1 | c.4260+6G>T | Splice Region (SNP) | VAF 41/575 reads (7%) | called by muse, mutect2
- EML4 | c.2327G>T p.G776V | Missense Mutation (SNP) | VAF 16/151 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EN2 | c.656G>C p.C219S | Missense Mutation (SNP) | VAF 16/231 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.171); called by muse, mutect2
- ENPP7 | c.658G>A p.D220N | Missense Mutation (SNP) | VAF 30/364 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); called by muse, mutect2
- ERBB4 | c.3815G>C p.G1272A | Missense Mutation (SNP) | VAF 10/215 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.433); called by muse, mutect2
- ETHE1 | c.64C>A p.P22T | Missense Mutation (SNP) | VAF 36/266 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EZH1 | c.763G>T p.E255* | Nonsense Mutation (SNP) | VAF 19/142 reads (13%) | called by muse, mutect2, varscan2
- FAM166C | c.238C>A p.L80I | Missense Mutation (SNP) | VAF 39/415 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.396); called by muse, mutect2
- FASN | c.5053A>T p.I1685F | Missense Mutation (SNP) | VAF 24/282 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- FCER1A | c.382C>A p.L128I | Missense Mutation (SNP) | VAF 23/308 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.34); called by muse, mutect2
- FCGR2B | c.636C>G p.I212M | Missense Mutation (SNP) | VAF 9/168 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FER1L6 | c.4305C>A p.D1435E | Missense Mutation (SNP) | VAF 26/225 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FIG4 | c.2671G>T p.G891* | Nonsense Mutation (SNP) | VAF 21/259 reads (8%) | called by muse, mutect2
- FLG2 | c.6506G>T p.G2169V | Missense Mutation (SNP) | VAF 30/377 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2
- FMNL1 | c.2820G>A p.M940I | Missense Mutation (SNP) | VAF 18/313 reads (6%) | SIFT tolerated (0.48); PolyPhen benign (0.015); called by muse, mutect2
- FOXJ1 | c.830C>A p.P277Q | Missense Mutation (SNP) | VAF 5/93 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.28); called by muse, mutect2
- FOXL1 | c.862G>C p.G288R | Missense Mutation (SNP) | VAF 18/204 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2
- FPGT | c.1716T>A p.Y572* | Nonsense Mutation (SNP) | VAF 15/179 reads (8%) | called by muse, mutect2
- FSIP2 | c.8434C>A p.P2812T | Missense Mutation (SNP) | VAF 10/143 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2
- GABRA6 | c.19T>A p.W7R | Missense Mutation (SNP) | VAF 22/302 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.125); called by muse, mutect2
- GALNT13 | c.101G>T p.C34F | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.584); called by mutect2, varscan2
- GCC2 | c.3089C>G p.S1030* | Nonsense Mutation (SNP) | VAF 14/131 reads (11%) | called by muse, mutect2, varscan2
- GDF9 | c.47G>A p.W16* | Nonsense Mutation (SNP) | VAF 15/173 reads (9%) | called by muse, mutect2
- GGTLC1 | c.654A>C p.K218N | Missense Mutation (SNP) | VAF 32/546 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- GPC2 | c.1310G>T p.R437L | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GPR137B | c.40G>T p.G14C | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.531); called by muse, mutect2, varscan2
- GPR25 | c.117C>A p.Y39* | Nonsense Mutation (SNP) | VAF 21/238 reads (9%) | called by muse, mutect2
- GPRC6A | c.518C>A p.A173E | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- GRIK3 | c.1553C>A p.P518H | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- H3-5 | c.286A>G p.S96G | Missense Mutation (SNP) | VAF 30/268 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.592); called by muse, mutect2
- H3-5 | c.284C>T p.A95V | Missense Mutation (SNP) | VAF 28/264 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.89); called by muse, mutect2
- HDAC9 | c.730A>T p.R244W | Missense Mutation (SNP) | VAF 15/245 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2
- HELZ2 | c.228G>T p.W76C | Missense Mutation (SNP) | VAF 10/175 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.077); called by muse, mutect2
- HEPH | c.2362G>A p.E788K (on ENST00000343002; = p.E521K on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- HEPN1 | c.157T>C p.S53P | Missense Mutation (SNP) | VAF 21/318 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.943); called by muse, mutect2
- HMGCS2 | c.1031A>C p.E344A | Missense Mutation (SNP) | VAF 21/406 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.42); called by muse, mutect2
- HOXD3 | c.125G>C p.G42A | Missense Mutation (SNP) | VAF 14/298 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.026); called by muse, mutect2
- HSP90AA1 | c.1031C>T p.P344L | Missense Mutation (SNP) | VAF 52/373 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HYDIN | c.1810C>A p.P604T | Missense Mutation (SNP) | VAF 25/316 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.846); called by muse, mutect2
- IFNGR1 | c.1130A>C p.E377A | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.297); called by muse, mutect2
- IGDCC3 | c.788G>T p.G263V | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- IGFN1 | c.3062T>A p.L1021Q (on ENST00000295591 / NM_001367841.1; = p.L3478Q on NM_001164586.2) | Missense Mutation (SNP) | VAF 23/145 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IGHD | c.694A>T p.S232C | Missense Mutation (SNP) | VAF 46/415 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGHV3OR16-8 | c.48T>G p.G16= | Splice Region (SNP) | VAF 10/177 reads (6%) | called by muse, mutect2
- IGHV3OR16-8 | c.161G>A p.S54N | Missense Mutation (SNP) | VAF 28/460 reads (6%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); called by muse, mutect2
- IGKV3D-20 | c.175C>A p.Q59K | Missense Mutation (SNP) | VAF 33/593 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.282); called by muse, mutect2
- IGKV3D-20 | c.260G>T p.G87V | Missense Mutation (SNP) | VAF 24/392 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); called by muse, mutect2
- IL22RA1 | c.1140G>T p.Q380H | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- IL7R | c.1048C>A p.P350T | Missense Mutation (SNP) | VAF 31/296 reads (10%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.856); called by muse, mutect2
- IPO13 | c.2829G>T p.M943I | Missense Mutation (SNP) | VAF 16/265 reads (6%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, mutect2
- IRGC | c.713C>G p.S238C | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- ITIH6 | c.3389C>G p.P1130R | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- IWS1 | c.333G>C p.E111D | Missense Mutation (SNP) | VAF 18/182 reads (10%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.006); called by muse, mutect2
- KASH5 | c.1471G>T p.V491L | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- KCTD14 | c.491G>C p.R164P | Missense Mutation (SNP) | VAF 25/237 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KDM5A | c.4373C>T p.S1458F | Missense Mutation (SNP) | VAF 27/378 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2
- KIAA1549 | c.1927G>T p.E643* | Nonsense Mutation (SNP) | VAF 12/140 reads (9%) | called by muse, mutect2
- KIF1A | c.2282C>T p.P761L | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.323); called by muse, mutect2
- KIF21B | c.4716G>T p.W1572C (on ENST00000422435 / NM_001252100.2; = p.W1559C on NM_017596.4) | Missense Mutation (SNP) | VAF 78/538 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIF4B | c.3305G>A p.R1102K | Missense Mutation (SNP) | VAF 40/450 reads (9%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.673); called by muse, mutect2
- KLHL2 | c.1090T>C p.S364P | Missense Mutation (SNP) | VAF 35/420 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); called by muse, mutect2
- KLHL34 | c.1534A>T p.M512L | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.526); called by mutect2, varscan2
- KNG1 | c.1124T>C p.M375T | Missense Mutation (SNP) | VAF 38/534 reads (7%) | SIFT tolerated (0.44); PolyPhen benign (0.006); called by muse, mutect2
- KRT3 | c.1429G>A p.D477N | Missense Mutation (SNP) | VAF 27/282 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2
- KRTAP6-2 | c.116G>T p.G39V | Missense Mutation (SNP) | VAF 18/222 reads (8%) | PolyPhen probably damaging (0.994); called by muse, mutect2
- LANCL2 | c.1186-1G>A p.X396_splice | Splice Site (SNP) | VAF 13/198 reads (7%) | called by muse, mutect2
- LEPR | c.3035G>A p.C1012Y | Missense Mutation (SNP) | VAF 18/224 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.959); called by muse, mutect2
- LRIT2 | c.1444T>A p.Y482N | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRRC8D | c.601G>T p.G201* | Nonsense Mutation (SNP) | VAF 30/256 reads (12%) | called by muse, mutect2, varscan2
- LYPLAL1 | c.478-2A>T p.X160_splice | Splice Site (SNP) | VAF 18/102 reads (18%) | called by muse, varscan2
- LYZL6 | c.61C>A p.L21I | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2
- MAGEA11 | c.382G>T p.A128S | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- MAGEB18 | c.112C>A p.P38T | Missense Mutation (SNP) | VAF 9/149 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.029); called by muse, mutect2
- MAGI2 | c.1147G>T p.A383S | Missense Mutation (SNP) | VAF 13/268 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- MAP3K4 | c.440G>C p.R147P | Missense Mutation (SNP) | VAF 19/222 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- MBD1 | c.73G>T p.G25W | Missense Mutation (SNP) | VAF 25/273 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MCM10 | c.442C>G p.Q148E | Missense Mutation (SNP) | VAF 13/186 reads (7%) | SIFT tolerated (0.75); PolyPhen benign (0.003); called by muse, mutect2
- MEOX2 | c.62C>A p.P21Q | Missense Mutation (SNP) | VAF 57/170 reads (34%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.685); called by muse, mutect2, varscan2
- METTL11B | c.424G>T p.V142L | Missense Mutation (SNP) | VAF 72/438 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MFSD9 | c.740C>T p.T247I | Missense Mutation (SNP) | VAF 33/241 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- MGAM2 | c.4697G>T p.R1566I | Missense Mutation (SNP) | VAF 17/262 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MMP2 | c.521G>T p.G174V | Missense Mutation (SNP) | VAF 19/280 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- MRC1 | c.3815C>T p.S1272F | Missense Mutation (SNP) | VAF 17/544 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); called by muse, mutect2
- MYH8 | c.355-1G>T p.X119_splice | Splice Site (SNP) | VAF 30/397 reads (8%) | called by muse, mutect2
- MYLK | c.560G>T p.R187L | Missense Mutation (SNP) | VAF 37/450 reads (8%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.982); called by muse, mutect2
- N4BP2L2 | c.2350G>A p.V784M (on ENST00000674422; = p.V355M on NM_033111.4) | Missense Mutation (SNP) | VAF 13/218 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.36); called by muse, mutect2
- NALCN | c.4144C>A p.L1382M | Missense Mutation (SNP) | VAF 18/222 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NALCN | c.2322G>T p.Q774H | Missense Mutation (SNP) | VAF 24/310 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.189); called by muse, mutect2
- NAP1L4 | c.584T>A p.F195Y | Missense Mutation (SNP) | VAF 8/147 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.058); called by muse, mutect2
- NAPRT | c.1022+1G>T p.X341_splice | Splice Site (SNP) | VAF 10/61 reads (16%) | called by muse, mutect2, varscan2
- NBEA | c.7231G>T p.D2411Y | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2
- NCAPH | c.1587G>T p.R529S | Missense Mutation (SNP) | VAF 11/121 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.118); called by muse, mutect2
- NLGN1 | c.263C>A p.P88Q | Missense Mutation (SNP) | VAF 16/204 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- NLRP3 | c.500C>A p.T167K | Missense Mutation (SNP) | VAF 48/552 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2
- NLRP8 | c.2336T>C p.L779P | Missense Mutation (SNP) | VAF 13/141 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- NMUR2 | c.727-2A>T p.X243_splice | Splice Site (SNP) | VAF 13/118 reads (11%) | called by muse, mutect2, varscan2
- NPAP1 | c.1702C>A p.Q568K | Missense Mutation (SNP) | VAF 8/174 reads (5%) | SIFT tolerated (0.35); PolyPhen benign (0.02); called by muse, mutect2
- NPAS4 | c.1699T>A p.C567S | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.262); called by muse, mutect2
- NPC1L1 | c.3344C>A p.P1115Q | Missense Mutation (SNP) | VAF 24/430 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2
- NPIPB8 | c.69G>T p.E23D | Missense Mutation (SNP) | VAF 34/744 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.535); called by muse, mutect2
- NPY5R | c.757G>T p.E253* | Nonsense Mutation (SNP) | VAF 29/238 reads (12%) | called by muse, mutect2, varscan2
- NRG1 | c.1711A>T p.S571C (on ENST00000405005 / NM_013964.5; = p.S576C on NM_013956.5) | Missense Mutation (SNP) | VAF 22/346 reads (6%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.914); called by muse, mutect2
- NRXN1 | c.1223T>C p.L408P | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NT5C1B | c.1565C>A p.A522D (on ENST00000359846 / NM_001199086.2; = p.A462D on NM_033253.4) | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.348); called by muse, mutect2
- NTNG2 | c.1199T>A p.L400Q | Missense Mutation (SNP) | VAF 39/342 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NTS | c.131C>G p.S44* | Nonsense Mutation (SNP) | VAF 9/143 reads (6%) | called by muse, mutect2
- ODF2 | c.610A>T p.K204* (on ENST00000434106 / NM_153433.2; = p.K180* on NM_002540.5 and 4 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 8/170 reads (5%) | called by muse, mutect2
- OLFM1 | c.331G>T p.E111* | Nonsense Mutation (SNP) | VAF 15/118 reads (13%) | called by muse, mutect2, varscan2
- OR10J1 | c.515A>T p.K172M | Missense Mutation (SNP) | VAF 21/348 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.043); called by muse, mutect2
- OR10T2 | c.256C>A p.L86M | Missense Mutation (SNP) | VAF 18/212 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR2A25 | c.604G>T p.A202S | Missense Mutation (SNP) | VAF 18/366 reads (5%) | SIFT tolerated (1); PolyPhen possibly damaging (0.794); called by muse, mutect2
- OR2B2 | c.216C>A p.C72* | Nonsense Mutation (SNP) | VAF 7/92 reads (8%) | called by muse, mutect2
- OR2C1 | c.442G>T p.A148S | Missense Mutation (SNP) | VAF 20/260 reads (8%) | SIFT tolerated (0.52); PolyPhen benign (0.262); called by muse, mutect2
- OR2J2 | c.808G>T p.D270Y | Missense Mutation (SNP) | VAF 22/202 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- OR2L5 | c.758C>A p.P253H | Missense Mutation (SNP) | VAF 19/239 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- OR4C15 | c.565A>T p.M189L (on ENST00000314644; = p.M135L on NM_001001920.2) | Missense Mutation (SNP) | VAF 17/163 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.495); called by muse, mutect2, varscan2
- OR4D9 | c.188T>A p.L63H | Missense Mutation (SNP) | VAF 17/153 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR51G2 | c.460C>A p.L154M | Missense Mutation (SNP) | VAF 10/107 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.249); called by muse, mutect2
- OR52N4 | c.76_77del p.Q26Tfs*28 | Frame Shift Del (DEL) | VAF 18/126 reads (14%) | called by pindel, varscan2
- OR5I1 | c.581C>A p.T194K | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- OR6X1 | c.559T>C p.C187R | Missense Mutation (SNP) | VAF 13/192 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- OR8K5 | c.244C>G p.L82V | Missense Mutation (SNP) | VAF 11/180 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.632); called by muse, mutect2
- OTUD7B | c.1789A>T p.S597C | Missense Mutation (SNP) | VAF 21/455 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); called by muse, mutect2
- OTX1 | c.746G>T p.S249I | Missense Mutation (SNP) | VAF 46/448 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); called by muse, mutect2
- PARVB | c.582G>T p.R194S | Missense Mutation (SNP) | VAF 15/177 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.027); called by muse, mutect2
- PAX1 | c.454G>T p.A152S | Missense Mutation (SNP) | VAF 15/325 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PAXBP1 | c.1264G>T p.D422Y | Missense Mutation (SNP) | VAF 28/238 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.648); called by muse, varscan2
- PCDH11X | c.52G>T p.V18L | Missense Mutation (SNP) | VAF 29/240 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.028); called by muse, varscan2
- PCDH7 | c.1253_1290del p.R418Qfs*66 | Frame Shift Del (DEL) | VAF 16/216 reads (7%) | called by mutect2, pindel
- PCDHGB5 | c.726C>A p.F242L | Missense Mutation (SNP) | VAF 20/186 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDHGB5 | c.917A>T p.E306V | Missense Mutation (SNP) | VAF 15/188 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PHF21B | c.935C>A p.A312D | Missense Mutation (SNP) | VAF 20/191 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2
- PIK3R4 | c.1795G>C p.D599H | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2
- PLCL1 | c.1847G>T p.S616I | Missense Mutation (SNP) | VAF 27/169 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- PLXDC1 | c.295C>G p.P99A | Missense Mutation (SNP) | VAF 14/237 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2
- PLXNB2 | c.3750G>T p.K1250N | Missense Mutation (SNP) | VAF 19/194 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- POLR1B | c.521G>T p.G174V | Missense Mutation (SNP) | VAF 13/230 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- POP1 | c.2352G>T p.E784D | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- PPP2R3B | c.148G>T p.G50W | Missense Mutation (SNP) | VAF 7/97 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); called by muse, mutect2
- PRKN | c.1063G>C p.G355R | Missense Mutation (SNP) | VAF 10/212 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.72); called by muse, mutect2
- PRSS41 | c.679A>T p.N227Y | Missense Mutation (SNP) | VAF 18/213 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.278); called by muse, mutect2
- PRSS55 | c.140C>A p.P47H | Missense Mutation (SNP) | VAF 11/116 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.059); called by muse, mutect2
- PRSS56 | c.352T>C p.W118R | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PSD | c.556G>T p.D186Y | Missense Mutation (SNP) | VAF 13/154 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.241); called by muse, mutect2
- PTCHD1 | c.1455T>A p.C485* | Nonsense Mutation (SNP) | VAF 18/200 reads (9%) | called by muse, mutect2
- PTPN14 | c.806T>C p.V269A | Missense Mutation (SNP) | VAF 22/356 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.133); called by muse, mutect2
- RAMP3 | c.293G>T p.R98M | Missense Mutation (SNP) | VAF 34/470 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- RANBP3L | c.626G>A p.S209N | Missense Mutation (SNP) | VAF 15/199 reads (8%) | SIFT tolerated (0.6); PolyPhen benign (0.051); called by muse, mutect2
- RBFOX2 | c.609G>C p.G203= (on ENST00000438146 / NM_001349995.2; = p.G133= on NM_014309.4 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 10/118 reads (8%) | called by muse, mutect2
- REP15 | c.583G>T p.G195W | Missense Mutation (SNP) | VAF 22/256 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.81); called by muse, mutect2
- RFTN2 | c.221A>G p.Y74C | Missense Mutation (SNP) | VAF 12/227 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2
- RGCC | c.411G>T p.M137I | Missense Mutation (SNP) | VAF 19/227 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); called by muse, mutect2
- RGS16 | c.107C>T p.T36I | Missense Mutation (SNP) | VAF 23/317 reads (7%) | SIFT tolerated (0.45); PolyPhen benign (0.003); called by muse, mutect2
- RNF2 | c.7C>T p.Q3* | Nonsense Mutation (SNP) | VAF 22/235 reads (9%) | called by muse, mutect2
- RORB | c.705G>C p.L235F (on ENST00000396204 / NM_001365023.1; = p.L224F on NM_006914.4) | Missense Mutation (SNP) | VAF 16/143 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.013); called by muse, varscan2
- RPH3A | c.885G>A p.G295= (on ENST00000389385 / NM_001143854.2; = p.G291= on NM_014954.4 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 12/141 reads (9%) | called by muse, mutect2
- RPL7 | c.707G>T p.R236M | Missense Mutation (SNP) | VAF 26/215 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- RSBN1L | c.1979A>G p.Y660C | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0.034); called by muse, mutect2
- RYR2 | c.11174T>A p.L3725Q | Missense Mutation (SNP) | VAF 19/157 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SAGE1 | c.1378G>C p.V460L | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- SALL1 | c.1376G>T p.G459V | Missense Mutation (SNP) | VAF 22/207 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SCMH1 | c.236C>A p.T79K (on ENST00000326197 / NM_001031694.2; = p.T32K on NM_012236.4) | Missense Mutation (SNP) | VAF 19/240 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); called by muse, mutect2
- SCN3A | c.4406A>G p.D1469G | Missense Mutation (SNP) | VAF 24/310 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2
- SDK1 | c.2165G>T p.G722V | Missense Mutation (SNP) | VAF 13/226 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); called by muse, mutect2
- SEMA5A | c.2981A>T p.Q994L | Missense Mutation (SNP) | VAF 69/434 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- SEMA5B | c.1918G>C p.D640H | Missense Mutation (SNP) | VAF 10/141 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- SENP5 | c.253G>T p.A85S | Missense Mutation (SNP) | VAF 13/196 reads (7%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.129); called by muse, mutect2
- SEPTIN14 | c.100G>T p.G34C | Missense Mutation (SNP) | VAF 14/139 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SERPINA10 | c.653C>A p.P218H | Missense Mutation (SNP) | VAF 29/239 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- SETD1B | c.3229G>C p.E1077Q | Missense Mutation (SNP) | VAF 10/160 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.581); called by muse, mutect2
- SF3A2 | c.719G>T p.G240V | Missense Mutation (SNP) | VAF 18/137 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- SFTPA2 | c.708G>T p.R236S | Missense Mutation (SNP) | VAF 15/208 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); called by muse, mutect2
- SFTPA2 | c.707G>T p.R236M | Missense Mutation (SNP) | VAF 14/206 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2
- SH3RF3 | c.2364G>T p.M788I | Missense Mutation (SNP) | VAF 7/122 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.025); called by muse, mutect2
- SHISA2 | c.632G>T p.G211V | Missense Mutation (SNP) | VAF 28/328 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.825); called by muse, mutect2
- SIK3 | c.1220-2A>T p.X407_splice (on ENST00000445177 / NM_001366686.2; = p.X414_splice on NM_025164.6 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 17/206 reads (8%) | called by muse, mutect2
- SLC16A9 | c.838A>G p.K280E | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.76); called by muse, mutect2
- SLC1A6 | c.936G>A p.W312* | Nonsense Mutation (SNP) | VAF 8/67 reads (12%) | called by muse, varscan2
- SLC7A11 | c.1381G>A p.V461I | Missense Mutation (SNP) | VAF 24/238 reads (10%) | SIFT tolerated (0.7); PolyPhen benign (0.007); called by muse, mutect2
- SLC8A2 | c.2627G>A p.R876Q | Missense Mutation (SNP) | VAF 26/227 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- SLCO2B1 | c.499del p.A167Pfs*20 | Frame Shift Del (DEL) | VAF 15/132 reads (11%) | called by mutect2, pindel
- SLF2 | c.1795G>T p.G599C | Missense Mutation (SNP) | VAF 28/330 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2
- SLIT1 | c.2513C>G p.S838C | Missense Mutation (SNP) | VAF 23/246 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- SLITRK5 | c.1060G>T p.G354C | Missense Mutation (SNP) | VAF 17/208 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.155); called by muse, mutect2
- SLITRK6 | c.2280A>T p.L760F | Missense Mutation (SNP) | VAF 20/204 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, mutect2
- SLITRK6 | c.209G>T p.S70I | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT tolerated (0.46); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- SPATA18 | c.1115A>C p.E372A | Missense Mutation (SNP) | VAF 10/206 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SPATA31A6 | c.160C>G p.P54A | Missense Mutation (SNP) | VAF 42/286 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.038); called by muse, varscan2
- SPATA31E1 | c.664T>A p.S222T | Missense Mutation (SNP) | VAF 20/143 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SPHKAP | c.1342C>A p.P448T | Missense Mutation (SNP) | VAF 34/270 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPRED3 | c.874G>C p.E292Q | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.53); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- SPTBN1 | c.6901G>A p.A2301T | Missense Mutation (SNP) | VAF 29/280 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- SRP72 | c.1992G>T p.K664N | Missense Mutation (SNP) | VAF 28/254 reads (11%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- SRPK2 | c.1264G>A p.E422K | Missense Mutation (SNP) | VAF 26/326 reads (8%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2
- SRPX | c.568C>A p.R190S | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.306); called by muse, mutect2
- STAB2 | c.250C>A p.L84I | Missense Mutation (SNP) | VAF 29/239 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- STAB2 | c.2878del p.Q960Kfs*55 | Frame Shift Del (DEL) | VAF 19/179 reads (11%) | called by mutect2, pindel
- STAT1 | c.1501G>A p.V501M | Missense Mutation (SNP) | VAF 15/407 reads (4%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.848); called by muse, mutect2
- STIL | c.425G>A p.S142N | Missense Mutation (SNP) | VAF 23/352 reads (7%) | SIFT tolerated (0.71); PolyPhen benign (0.003); called by muse, mutect2
- STT3A | c.397del p.H133Tfs*18 | Frame Shift Del (DEL) | VAF 22/262 reads (8%) | called by mutect2, pindel
- SVIL | c.2553A>T p.Q851H (on ENST00000355867 / NM_021738.3; = p.Q425H on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/253 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SYNE2 | c.17605C>T p.Q5869* | Nonsense Mutation (SNP) | VAF 55/509 reads (11%) | called by muse, mutect2, varscan2
- SYNE2 | c.19456C>T p.P6486S | Missense Mutation (SNP) | VAF 58/426 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- SYNPO2 | c.3621G>T p.M1207I | Missense Mutation (SNP) | VAF 40/401 reads (10%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2, varscan2
- TAAR8 | c.617T>C p.F206S | Missense Mutation (SNP) | VAF 17/194 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2
- TAOK3 | c.398A>C p.H133P | Missense Mutation (SNP) | VAF 13/176 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2
- TBC1D9B | c.254A>T p.K85I | Missense Mutation (SNP) | VAF 20/206 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- TBX18 | c.575T>A p.V192E | Missense Mutation (SNP) | VAF 17/148 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- TBX3 | c.485G>T p.R162L | Missense Mutation (SNP) | VAF 29/416 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- TBX3 | c.484C>A p.R162S | Missense Mutation (SNP) | VAF 30/418 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- TCEAL2 | c.564G>T p.L188F | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); called by muse, mutect2
- TCF20 | c.4151A>G p.D1384G | Missense Mutation (SNP) | VAF 12/226 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); called by muse, mutect2
- TECRL | c.1016del p.K339Rfs*7 | Frame Shift Del (DEL) | VAF 20/194 reads (10%) | called by mutect2, pindel
- TERT | c.2003A>T p.E668V | Missense Mutation (SNP) | VAF 19/187 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TEX46 | c.286C>T p.P96S | Missense Mutation (SNP) | VAF 10/173 reads (6%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.028); called by muse, mutect2
- TEX51 | c.496G>C p.V166L (on ENST00000643416; = p.V142L on NM_001322244.2) | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.992); called by muse, mutect2
- TFAP2B | c.504del p.H169Tfs*22 | Frame Shift Del (DEL) | VAF 24/228 reads (11%) | called by mutect2, pindel*, varscan2
- TGM5 | c.2010-2A>T p.X670_splice (on ENST00000220420 / NM_201631.4; = p.X588_splice on NM_004245.4) | Splice Site (SNP) | VAF 33/413 reads (8%) | called by muse, mutect2
- THSD4 | c.842C>A p.S281Y | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.191); called by muse, mutect2
- TLCD2 | c.283G>T p.D95Y | Missense Mutation (SNP) | VAF 18/208 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2
- TMEM39B | c.407G>T p.R136L | Missense Mutation (SNP) | VAF 24/335 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TMEM81 | c.160G>T p.G54C | Missense Mutation (SNP) | VAF 36/260 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TNK2 | c.262G>C p.E88Q | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.031); called by muse, mutect2
- TNR | c.1453G>T p.V485L | Missense Mutation (SNP) | VAF 17/286 reads (6%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.772); called by muse, mutect2
- TRABD2B | c.1495C>A p.P499T | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); called by muse, mutect2
- TRIM40 | c.206A>T p.Y69F | Missense Mutation (SNP) | VAF 22/392 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.009); called by muse, mutect2
- TRIM49 | c.313G>C p.E105Q | Missense Mutation (SNP) | VAF 14/384 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.817); called by muse, mutect2
- TRIM49C | c.929G>T p.C310F | Missense Mutation (SNP) | VAF 24/465 reads (5%) | SIFT tolerated (0.37); PolyPhen benign (0.09); called by muse, mutect2
- TRPM6 | c.2686G>T p.G896W | Missense Mutation (SNP) | VAF 25/266 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2
- TRPM8 | c.1306T>A p.W436R | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TRPV5 | c.680A>T p.D227V | Missense Mutation (SNP) | VAF 47/329 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- TTN | c.52880C>T p.P17627L (on ENST00000591111; = p.P10203L on NM_003319.4) | Missense Mutation (SNP) | VAF 40/524 reads (8%) | PolyPhen probably damaging (0.999); called by muse, mutect2
- TUBA1B | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 16/316 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- UBE2U | c.846G>C p.E282D | Missense Mutation (SNP) | VAF 23/238 reads (10%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.686); called by muse, mutect2
- UGGT2 | c.4347G>T p.W1449C | Missense Mutation (SNP) | VAF 8/234 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- UGT2B7 | c.1068G>T p.W356C | Missense Mutation (SNP) | VAF 15/274 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.085); called by muse, mutect2
- UGT3A1 | c.165G>T p.M55I | Missense Mutation (SNP) | VAF 20/174 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- UGT8 | c.412G>T p.D138Y | Missense Mutation (SNP) | VAF 30/280 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- UMOD | c.196C>A p.L66M | Missense Mutation (SNP) | VAF 33/482 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.051); called by muse, mutect2
- UNC80 | c.5212C>T p.Q1738* | Nonsense Mutation (SNP) | VAF 20/210 reads (10%) | called by muse, mutect2
- UROC1 | c.628T>C p.Y210H | Missense Mutation (SNP) | VAF 32/341 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2
- USF2 | c.512C>A p.P171Q | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2
- USP2 | c.1731C>G p.S577R | Missense Mutation (SNP) | VAF 20/261 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- USP34 | c.2192G>T p.G731V | Missense Mutation (SNP) | VAF 15/252 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.108); called by muse, mutect2
- VAV2 | c.2461G>T p.A821S (on ENST00000371850 / NM_001134398.2; = p.A782S on NM_003371.4) | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); called by muse, mutect2
- VNN1 | c.661G>T p.V221F | Missense Mutation (SNP) | VAF 12/184 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- VPS50 | c.102+6G>T | Splice Region (SNP) | VAF 20/216 reads (9%) | called by muse, mutect2
- VSIG1 | c.725G>A p.G242D | Missense Mutation (SNP) | VAF 9/113 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- WIPF3 | c.591A>T p.K197N | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.19); called by muse, mutect2
- WRN | c.3834G>C p.E1278D | Missense Mutation (SNP) | VAF 17/249 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.015); called by muse, mutect2
- XIRP2 | c.2455C>A p.P819T (on ENST00000628543; = p.P994T on NM_152381.6) | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- XRN1 | c.1746C>G p.N582K | Missense Mutation (SNP) | VAF 23/242 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.028); called by muse, mutect2
- ZAR1L | c.175T>A p.C59S | Missense Mutation (SNP) | VAF 43/393 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ZDBF2 | c.1858A>T p.S620C | Missense Mutation (SNP) | VAF 12/214 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2
- ZDBF2 | c.4615G>C p.V1539L | Missense Mutation (SNP) | VAF 22/280 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.038); called by muse, mutect2
- ZEB1 | c.2894G>A p.C965Y | Missense Mutation (SNP) | VAF 30/492 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZG16B | c.139G>T p.G47W | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.029); called by muse, mutect2
- ZNF112 | c.611A>G p.K204R (on ENST00000337401 / NM_001083335.2; = p.K198R on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, varscan2
- ZNF208 | c.1124G>T p.G375V | Missense Mutation (SNP) | VAF 31/328 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF385C | c.323C>A p.P108Q | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ZNF385D | c.1045G>T p.V349L | Missense Mutation (SNP) | VAF 24/348 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.007); called by muse, mutect2
- ZNF43 | c.928G>T p.G310* | Nonsense Mutation (SNP) | VAF 26/313 reads (8%) | called by muse, mutect2
- ZNF469 | c.547T>A p.C183S | Missense Mutation (SNP) | VAF 40/572 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.71); called by muse, mutect2
- ZNF492 | c.1454C>A p.A485D | Missense Mutation (SNP) | VAF 24/284 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.97); called by muse, mutect2
- ZNF518A | c.728G>T p.C243F | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.078); called by muse, mutect2
- ZNF532 | c.1937G>T p.C646F | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNRF3 | c.2384G>T p.S795I (on ENST00000544604 / NM_001206998.2; = p.S695I on NM_032173.3) | Missense Mutation (SNP) | VAF 14/172 reads (8%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.005); called by muse, mutect2
- ZP4 | c.1373C>A p.T458N | Missense Mutation (SNP) | VAF 22/175 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- ABCA13 | c.4890T>A p.L1630= | Silent (SNP) | VAF 32/363 reads (9%) | called by muse, mutect2
- AC132217.2 | c.231G>T p.G77= | Silent (SNP) | VAF 13/154 reads (8%) | catalogued as COSV56097854; called by muse, mutect2
- ACAN | c.2400C>A p.S800= | Silent (SNP) | VAF 10/66 reads (15%) | called by muse, mutect2, varscan2
- ACE | c.3561G>A p.T1187= | Silent (SNP) | VAF 42/430 reads (10%) | catalogued as rs141429845; called by muse, mutect2
- ADAMTS6 | c.3030C>A p.I1010= | Silent (SNP) | VAF 26/250 reads (10%) | catalogued as COSV58685340; called by muse, mutect2
- ADGRE1 | c.831A>C p.S277= | Silent (SNP) | VAF 22/207 reads (11%) | called by muse, mutect2, varscan2
- AKAP12 | c.4134G>T p.V1378= | Silent (SNP) | VAF 14/281 reads (5%) | catalogued as COSV53572981; called by muse, mutect2
- AL121899.2 | c.801G>A p.R267= | Silent (SNP) | VAF 21/287 reads (7%) | called by muse, mutect2
- AL645922.1 | c.1122C>A p.S374= | Silent (SNP) | VAF 30/348 reads (9%) | catalogued as COSV54963585; called by muse, mutect2
- ALK | c.1008G>T p.P336= | Silent (SNP) | VAF 32/639 reads (5%) | called by muse, mutect2
- ANK2 | c.4578T>C p.S1526= | Silent (SNP) | VAF 23/306 reads (8%) | called by muse, mutect2
- ANK3 | c.9603C>T p.P3201= | Silent (SNP) | VAF 21/225 reads (9%) | catalogued as rs150889156, COSV55076441; called by muse, mutect2
- ANKRD11 | c.6243C>T p.P2081= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as rs757119978; called by muse, mutect2, varscan2
- ANKRD33B | c.1171C>T p.L391= | Silent (SNP) | VAF 6/31 reads (19%) | called by mutect2, varscan2
- ARFGEF3 | c.3285G>T p.R1095= | Silent (SNP) | VAF 5/48 reads (10%) | called by muse, mutect2
- ARHGAP11B | c.510A>G p.V170= | Silent (SNP) | VAF 24/409 reads (6%) | called by muse, mutect2
- ARHGAP36 | c.642A>T p.P214= | Silent (SNP) | VAF 6/47 reads (13%) | called by muse, mutect2, varscan2
- ARMC4 | c.1125C>A p.T375= | Silent (SNP) | VAF 16/218 reads (7%) | catalogued as rs770479946, COSV99518437; called by muse, mutect2
- ARSF | c.1230C>A p.V410= | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as COSV100839442; called by mutect2, varscan2
- ASB2 | c.975G>A p.L325= | Silent (SNP) | VAF 6/76 reads (8%) | catalogued as rs1268661231; called by muse, mutect2
- ATRNL1 | c.3942G>T p.G1314= | Silent (SNP) | VAF 12/242 reads (5%) | called by muse, mutect2
- B3GALT5 | c.543T>A p.T181= | Silent (SNP) | VAF 19/192 reads (10%) | called by muse, mutect2, varscan2
- BCAS1 | c.1407C>A p.S469= | Silent (SNP) | VAF 16/218 reads (7%) | called by muse, mutect2
- BSCL2 | c.552C>T p.Y184= | Silent (SNP) | VAF 30/517 reads (6%) | catalogued as rs766655185, COSV54015466; called by muse, mutect2
- CACNA1G | c.1878C>G p.P626= | Silent (SNP) | VAF 27/363 reads (7%) | catalogued as rs369327128; called by muse, mutect2
- CD36 | c.297C>A p.A99= | Silent (SNP) | VAF 23/282 reads (8%) | catalogued as COSV59217983; called by muse, mutect2
- CDH12 | c.2265C>T p.D755= | Silent (SNP) | VAF 34/395 reads (9%) | called by muse, mutect2
- CDH4 | c.255C>A p.V85= | Silent (SNP) | VAF 31/384 reads (8%) | called by muse, mutect2
- CDX4 | c.489G>T p.T163= | Silent (SNP) | VAF 8/24 reads (33%) | called by mutect2, varscan2
- CEBPE | c.777C>A p.T259= | Silent (SNP) | VAF 15/192 reads (8%) | catalogued as COSV99247319; called by muse, mutect2
- CELF5 | c.156C>A p.I52= | Silent (SNP) | VAF 21/264 reads (8%) | called by muse, mutect2
- CHI3L2 | c.237G>C p.V79= | Silent (SNP) | VAF 14/206 reads (7%) | called by muse, mutect2
- CIITA | c.3099C>T p.Y1033= | Silent (SNP) | VAF 16/230 reads (7%) | catalogued as rs1397847491; called by muse, mutect2
- CNTN2 | c.717C>A p.P239= | Silent (SNP) | VAF 34/330 reads (10%) | called by muse, mutect2, varscan2
- COL26A1 | c.204G>T p.V68= | Silent (SNP) | VAF 16/266 reads (6%) | called by muse, mutect2
- COL5A3 | c.4950C>T p.S1650= | Silent (SNP) | VAF 30/252 reads (12%) | called by muse, mutect2, varscan2
- CRMP1 | c.789C>A p.I263= | Silent (SNP) | VAF 20/354 reads (6%) | called by muse, mutect2
- CYP2S1 | c.1170G>T p.T390= | Silent (SNP) | VAF 11/78 reads (14%) | called by mutect2, varscan2
- DAZL | c.39C>T p.I13= | Silent (SNP) | VAF 34/342 reads (10%) | called by muse, mutect2
- DDX24 | c.1530C>A p.L510= | Silent (SNP) | VAF 27/326 reads (8%) | catalogued as COSV58212905; called by muse, mutect2
- DGAT2L6 | c.768C>A p.I256= | Silent (SNP) | VAF 20/183 reads (11%) | called by muse, varscan2
- DLGAP2 | c.1674C>A p.A558= | Silent (SNP) | VAF 16/168 reads (10%) | called by muse, mutect2
- DMD | c.1767C>A p.G589= | Silent (SNP) | VAF 20/189 reads (11%) | called by muse, mutect2, varscan2
- DROSHA | c.1359G>T p.G453= | Silent (SNP) | VAF 12/206 reads (6%) | catalogued as COSV100757557; called by muse, mutect2
- DVL3 | c.498G>T p.R166= | Silent (SNP) | VAF 12/206 reads (6%) | called by muse, mutect2
- DZIP3 | c.2529C>T p.S843= | Silent (SNP) | VAF 16/208 reads (8%) | called by muse, mutect2
- ELOA2 | c.1161C>A p.L387= | Silent (SNP) | VAF 20/274 reads (7%) | called by muse, mutect2
- EMSY | c.3342C>T p.P1114= | Silent (SNP) | VAF 12/100 reads (12%) | called by muse, varscan2
- F10 | c.618C>A p.A206= | Silent (SNP) | VAF 20/255 reads (8%) | called by muse, mutect2
- FAM234B | c.570G>T p.S190= | Silent (SNP) | VAF 9/93 reads (10%) | called by muse, mutect2
- FAM47A | c.600C>A p.L200= | Silent (SNP) | VAF 8/72 reads (11%) | called by muse, varscan2
- FAT1 | c.3081G>A p.E1027= | Silent (SNP) | VAF 18/186 reads (10%) | called by muse, mutect2
- FBXL18 | c.561G>T p.V187= | Silent (SNP) | VAF 8/81 reads (10%) | called by muse, mutect2, varscan2
- FBXO21 | c.1809G>T p.R603= (on ENST00000330622 / NM_033624.3; = p.R596= on NM_015002.3) | Silent (SNP) | VAF 16/185 reads (9%) | called by muse, mutect2
- FER1L6 | c.2343G>C p.L781= | Silent (SNP) | VAF 21/255 reads (8%) | called by muse, mutect2
- FOXL1 | c.306G>T p.S102= | Silent (SNP) | VAF 36/520 reads (7%) | catalogued as rs760715335; called by muse, mutect2
- FRMPD1 | c.3045C>T p.L1015= | Silent (SNP) | VAF 22/253 reads (9%) | called by muse, mutect2
- FSIP2 | c.3633C>A p.V1211= | Silent (SNP) | VAF 11/80 reads (14%) | called by muse, mutect2, varscan2
- GLIS3 | c.1089G>T p.V363= | Silent (SNP) | VAF 18/234 reads (8%) | called by muse, mutect2
- GPR158 | c.2592C>T p.D864= | Silent (SNP) | VAF 17/253 reads (7%) | called by muse, mutect2
- GRAMD1B | c.1755G>T p.T585= | Silent (SNP) | VAF 20/174 reads (11%) | catalogued as rs1351653711, COSV59204751; called by muse, mutect2
- HCN1 | c.2103C>G p.T701= | Silent (SNP) | VAF 18/150 reads (12%) | catalogued as rs762033519, COSV57518789, COSV57525369; called by muse, mutect2, varscan2
- HDAC9 | c.111G>T p.V37= | Silent (SNP) | VAF 23/346 reads (7%) | called by muse, mutect2
- HECW1 | c.2389C>A p.R797= | Silent (SNP) | VAF 6/46 reads (13%) | called by muse, varscan2
- HOXD11 | c.930C>G p.V310= | Silent (SNP) | VAF 31/395 reads (8%) | called by muse, mutect2
- HYDIN | c.12906C>A p.I4302= | Silent (SNP) | VAF 7/118 reads (6%) | called by muse, mutect2
- IRF2BP1 | c.699A>T p.L233= | Silent (SNP) | VAF 57/265 reads (22%) | called by muse, mutect2, varscan2
- ISLR2 | c.303C>A p.L101= | Silent (SNP) | VAF 21/251 reads (8%) | catalogued as COSV62301990; called by muse, mutect2
- JRK | c.645G>T p.R215= | Silent (SNP) | VAF 34/230 reads (15%) | called by muse, mutect2, varscan2
- KCNK13 | c.1125C>A p.P375= | Silent (SNP) | VAF 8/132 reads (6%) | catalogued as COSV99965534; called by muse, mutect2
- KCNK9 | c.843C>A p.P281= | Silent (SNP) | VAF 14/239 reads (6%) | called by muse, mutect2
- KIRREL3 | c.666C>A p.G222= | Silent (SNP) | VAF 5/99 reads (5%) | catalogued as COSV73104820; called by muse, mutect2
- KIZ | c.111G>T p.L37= | Silent (SNP) | VAF 17/157 reads (11%) | called by muse, varscan2
- KRT71 | c.591G>C p.G197= | Silent (SNP) | VAF 28/375 reads (7%) | called by muse, mutect2
- LGI2 | c.1140T>C p.D380= | Silent (SNP) | VAF 8/142 reads (6%) | catalogued as COSV101180783; called by muse, mutect2
- LIPG | c.558G>A p.V186= | Silent (SNP) | VAF 25/428 reads (6%) | called by muse, mutect2
- LPA | c.2745T>A p.T915= | Silent (SNP) | VAF 24/715 reads (3%) | called by muse, mutect2
- LPCAT1 | c.1293A>G p.Q431= | Silent (SNP) | VAF 12/105 reads (11%) | called by muse, mutect2, varscan2
- LRRC7 | c.2460G>A p.E820= (on ENST00000651989 / NM_001370785.2; = p.E787= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 13/216 reads (6%) | catalogued as rs1489384419; called by muse, mutect2
- LRRN2 | c.1347C>G p.A449= | Silent (SNP) | VAF 18/72 reads (25%) | catalogued as COSV100912953; called by muse, mutect2, varscan2
- MC1R | c.465C>T p.I155= | Silent (SNP) | VAF 19/157 reads (12%) | catalogued as rs374878766, COSV59625030; called by muse, mutect2, varscan2
- ME1 | c.843C>A p.L281= | Silent (SNP) | VAF 19/156 reads (12%) | catalogued as COSV63838300; called by muse, mutect2, varscan2
- MGAM | c.3372C>A p.T1124= | Silent (SNP) | VAF 37/466 reads (8%) | catalogued as COSV72075298; called by muse, mutect2
- MLC1 | c.135C>A p.P45= | Silent (SNP) | VAF 34/443 reads (8%) | catalogued as rs76283012, CD151534; called by muse, mutect2
- MMP19 | c.366C>A p.P122= | Silent (SNP) | VAF 10/101 reads (10%) | called by muse, mutect2
- MMP26 | c.402G>C p.V134= | Silent (SNP) | VAF 10/205 reads (5%) | called by muse, mutect2
- MOSPD3 | c.516C>A p.P172= | Silent (SNP) | VAF 5/88 reads (6%) | called by muse, mutect2
- MYH3 | c.615G>A p.L205= | Silent (SNP) | VAF 30/380 reads (8%) | catalogued as rs752379531; called by muse, mutect2
- MYO15B | c.4390C>A p.R1464= | Silent (SNP) | VAF 6/60 reads (10%) | called by muse, mutect2
- NAV3 | c.621C>A p.S207= | Silent (SNP) | VAF 21/190 reads (11%) | called by muse, mutect2, varscan2
- NEBL | c.885C>T p.A295= | Silent (SNP) | VAF 35/370 reads (9%) | called by muse, mutect2
- NTNG1 | c.1110C>A p.S370= | Silent (SNP) | VAF 15/163 reads (9%) | called by muse, mutect2
- NUFIP2 | c.1008A>G p.L336= | Silent (SNP) | VAF 18/213 reads (8%) | catalogued as rs541584049; called by muse, mutect2
- ODF3L2 | c.213G>T p.S71= | Silent (SNP) | VAF 8/78 reads (10%) | called by mutect2, varscan2
- OGFR | c.651C>G p.L217= | Silent (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2
- OR2A25 | c.144C>T p.I48= | Silent (SNP) | VAF 69/465 reads (15%) | called by muse, mutect2, varscan2
- OR2J3 | c.513G>T p.L171= | Silent (SNP) | VAF 31/253 reads (12%) | called by muse, mutect2, varscan2
- OR6P1 | c.786C>A p.P262= | Silent (SNP) | VAF 29/447 reads (6%) | called by muse, mutect2
- P3H1 | c.336C>T p.G112= | Silent (SNP) | VAF 18/166 reads (11%) | called by muse, mutect2, varscan2
- PAPPA2 | c.613C>A p.R205= | Silent (SNP) | VAF 15/163 reads (9%) | catalogued as rs1467869802, COSV62775190; called by muse, mutect2
- PCDH10 | c.891G>T p.A297= | Silent (SNP) | VAF 28/298 reads (9%) | called by muse, mutect2
- PCDH8 | c.2946C>G p.A982= | Silent (SNP) | VAF 6/76 reads (8%) | called by muse, mutect2
- PCGF6 | c.873C>T p.F291= (on ENST00000369847 / NM_001011663.2; = p.F216= on NM_032154.4) | Silent (SNP) | VAF 14/164 reads (9%) | called by muse, mutect2
- PCGF6 | c.474C>T p.C158= | Silent (SNP) | VAF 8/122 reads (7%) | called by muse, mutect2
- PCNX3 | c.2694C>T p.F898= | Silent (SNP) | VAF 12/196 reads (6%) | catalogued as rs1156324903, COSV63139770; called by muse, mutect2
- PDE6A | c.759G>C p.T253= | Silent (SNP) | VAF 34/380 reads (9%) | called by muse, mutect2
- PEG3 | c.2994A>T p.G998= | Silent (SNP) | VAF 8/104 reads (8%) | called by muse, mutect2
- PEX1 | c.87C>T p.L29= | Silent (SNP) | VAF 13/172 reads (8%) | catalogued as rs1348692744; ClinVar: likely benign; called by muse, mutect2
- PKD1L3 | c.4977C>A p.V1659= | Silent (SNP) | VAF 10/185 reads (5%) | called by muse, mutect2
- PKHD1 | c.3339G>T p.L1113= | Silent (SNP) | VAF 16/310 reads (5%) | called by muse, mutect2
- PLEC | c.114G>T p.G38= | Silent (SNP) | VAF 12/111 reads (11%) | called by muse, mutect2, varscan2
- PLPPR4 | c.1260C>T p.A420= | Silent (SNP) | VAF 16/186 reads (9%) | called by muse, mutect2
- PLSCR5 | c.99A>T p.P33= | Silent (SNP) | VAF 16/258 reads (6%) | called by muse, mutect2
- POU4F1 | c.183G>T p.L61= | Silent (SNP) | VAF 6/37 reads (16%) | called by muse, mutect2, varscan2
- PRG4 | c.1344C>A p.P448= | Silent (SNP) | VAF 43/541 reads (8%) | called by muse, mutect2
- PRKAR1A | c.492G>T p.V164= | Silent (SNP) | VAF 34/461 reads (7%) | called by muse, mutect2
- PRX | c.3801G>A p.G1267= | Silent (SNP) | VAF 26/181 reads (14%) | catalogued as rs765275930; called by muse, mutect2, varscan2
- PTPRC | c.390C>T p.S130= | Silent (SNP) | VAF 26/469 reads (6%) | catalogued as rs895114528, COSV100722981; called by muse, mutect2
- RBM12 | c.726G>T p.S242= | Silent (SNP) | VAF 11/144 reads (8%) | catalogued as rs950331187; called by muse, mutect2
- RGPD3 | c.2250C>A p.V750= | Silent (SNP) | VAF 42/946 reads (4%) | called by muse, mutect2
- ROBO3 | c.18G>T p.L6= | Silent (SNP) | VAF 21/163 reads (13%) | catalogued as COSV67300388; called by muse, mutect2, varscan2
- RORB | c.756C>A p.T252= (on ENST00000396204 / NM_001365023.1; = p.T241= on NM_006914.4) | Silent (SNP) | VAF 18/136 reads (13%) | called by muse, varscan2
- RPGR | c.1908A>G p.S636= | Silent (SNP) | VAF 25/254 reads (10%) | called by muse, mutect2
- RRP8 | c.876A>C p.P292= | Silent (SNP) | VAF 11/112 reads (10%) | called by muse, mutect2
- SEMA3D | c.2064G>A p.Q688= | Silent (SNP) | VAF 34/457 reads (7%) | called by muse, mutect2
- SET | c.322C>T p.L108= (on ENST00000372692 / NM_001374326.1; = p.L95= on NM_003011.4) | Silent (SNP) | VAF 22/167 reads (13%) | called by muse, mutect2, varscan2
- SETBP1 | c.3651C>A p.A1217= | Silent (SNP) | VAF 34/568 reads (6%) | catalogued as rs755631153; called by muse, mutect2
- SIRPB1 | c.783C>A p.P261= | Silent (SNP) | VAF 8/137 reads (6%) | called by muse, mutect2
- SLAMF6 | c.288C>G p.L96= | Silent (SNP) | VAF 19/336 reads (6%) | called by muse, mutect2
- SLC32A1 | c.939C>A p.I313= | Silent (SNP) | VAF 27/372 reads (7%) | called by muse, mutect2
- SLC3A1 | c.330C>G p.L110= | Silent (SNP) | VAF 38/516 reads (7%) | catalogued as rs749428490; called by muse, mutect2
- SLC43A3 | c.1095G>T p.T365= | Silent (SNP) | VAF 12/79 reads (15%) | called by muse, mutect2, varscan2
- SLC4A1 | c.513G>T p.G171= | Silent (SNP) | VAF 52/534 reads (10%) | called by muse, mutect2
- SLC5A2 | c.1212C>G p.L404= | Silent (SNP) | VAF 15/146 reads (10%) | called by muse, mutect2, varscan2
- SLC8A2 | c.2626C>A p.R876= | Silent (SNP) | VAF 26/226 reads (12%) | catalogued as rs368439720; called by muse, varscan2
- SOBP | c.2556C>A p.A852= | Silent (SNP) | VAF 20/317 reads (6%) | called by muse, mutect2
- SPTA1 | c.3465T>A p.A1155= | Silent (SNP) | VAF 10/204 reads (5%) | called by muse, mutect2
- STK3 | c.42G>T p.L14= | Silent (SNP) | VAF 26/199 reads (13%) | called by muse, mutect2, varscan2
- STRC | c.4317T>A p.A1439= | Silent (SNP) | VAF 30/271 reads (11%) | called by muse, mutect2, varscan2
- SYT9 | c.432C>A p.I144= | Silent (SNP) | VAF 26/186 reads (14%) | called by muse, mutect2, varscan2
- TBX5 | c.123C>G p.S41= | Silent (SNP) | VAF 12/153 reads (8%) | called by muse, mutect2
- TDRD15 | c.606A>G p.Q202= | Silent (SNP) | VAF 10/122 reads (8%) | called by muse, mutect2
- TENM1 | c.96T>C p.D32= | Silent (SNP) | VAF 30/185 reads (16%) | catalogued as rs1242454869; called by muse, mutect2, varscan2
- TENM2 | c.2106G>A p.A702= (on ENST00000518659 / NM_001122679.2; = p.A470= on NM_001080428.3) | Silent (SNP) | VAF 16/194 reads (8%) | catalogued as rs752804454, COSV69134348; called by muse, mutect2
- TENM3 | c.7599C>T p.Y2533= | Silent (SNP) | VAF 28/326 reads (9%) | called by muse, mutect2
- TERT | c.2988G>A p.T996= | Silent (SNP) | VAF 69/543 reads (13%) | catalogued as rs776966669; called by muse, mutect2, varscan2
- TGFB3 | c.487C>A p.R163= | Silent (SNP) | VAF 22/340 reads (6%) | called by muse, mutect2
- THOP1 | c.805C>T p.L269= | Silent (SNP) | VAF 9/149 reads (6%) | called by muse, mutect2
- THSD7B | c.2244C>A p.P748= | Silent (SNP) | VAF 14/207 reads (7%) | called by muse, mutect2
- TMEM265 | c.75C>T p.C25= | Silent (SNP) | VAF 22/214 reads (10%) | called by muse, mutect2
- TMEM45A | c.546G>A p.L182= | Silent (SNP) | VAF 13/178 reads (7%) | called by muse, mutect2
- TMEM52B | c.186C>T p.S62= (on ENST00000381923 / NM_001079815.1; = p.S42= on NM_153022.4) | Silent (SNP) | VAF 12/102 reads (12%) | called by muse, varscan2
- TRIM64B | c.1236T>C p.Y412= | Silent (SNP) | VAF 36/644 reads (6%) | catalogued as rs1351277209; called by muse, mutect2
- TRPC6 | c.1266C>A p.L422= | Silent (SNP) | VAF 16/260 reads (6%) | called by muse, mutect2
- TRPM8 | c.1305G>A p.E435= | Silent (SNP) | VAF 11/194 reads (6%) | called by muse, mutect2
- TRPV5 | c.807G>T p.T269= | Silent (SNP) | VAF 29/245 reads (12%) | called by muse, mutect2, varscan2
- TSC2 | c.1731C>T p.T577= | Silent (SNP) | VAF 46/461 reads (10%) | catalogued as rs144122318; ClinVar: likely benign / benign; called by muse, mutect2
- TSSC4 | c.153G>A p.P51= | Silent (SNP) | VAF 23/198 reads (12%) | catalogued as rs911658851, COSV99329424; called by muse, mutect2, varscan2
- TWF1 | c.645C>T p.A215= | Silent (SNP) | VAF 10/88 reads (11%) | catalogued as rs1437897481; called by muse, varscan2
- TYK2 | c.1569C>T p.F523= | Silent (SNP) | VAF 15/183 reads (8%) | called by muse, mutect2
- UNC13C | c.1323C>T p.I441= | Silent (SNP) | VAF 19/192 reads (10%) | catalogued as COSV52892182; called by muse, mutect2
- URB1 | c.2736G>T p.L912= | Silent (SNP) | VAF 25/363 reads (7%) | called by muse, mutect2
- USH2A | c.3504C>G p.T1168= | Silent (SNP) | VAF 60/553 reads (11%) | catalogued as COSV56390280; called by muse, mutect2, varscan2
- VSTM2B | c.426C>A p.A142= | Silent (SNP) | VAF 24/372 reads (6%) | called by muse, mutect2
- VWF | c.8202C>G p.V2734= | Silent (SNP) | VAF 40/356 reads (11%) | catalogued as rs1339971429, COSV99780583; called by muse, mutect2, varscan2
- WDR38 | c.624C>A p.S208= | Silent (SNP) | VAF 20/147 reads (14%) | catalogued as COSV100793871; called by muse, mutect2, varscan2
- XKR6 | c.60G>T p.L20= | Silent (SNP) | VAF 14/222 reads (6%) | called by muse, mutect2
- YKT6 | c.399A>G p.P133= | Silent (SNP) | VAF 12/168 reads (7%) | called by muse, mutect2
- ZAN | c.7866C>A p.P2622= | Silent (SNP) | VAF 13/107 reads (12%) | called by muse, mutect2, varscan2
- ZBBX | c.1134A>T p.P378= | Silent (SNP) | VAF 20/174 reads (11%) | called by muse, mutect2, varscan2
- ZC3H12B | c.2070C>A p.P690= | Silent (SNP) | VAF 12/58 reads (21%) | called by muse, mutect2, varscan2
- ZDBF2 | c.1950G>A p.K650= | Silent (SNP) | VAF 25/251 reads (10%) | called by muse, mutect2, varscan2
- ZDBF2 | c.2160T>C p.D720= | Silent (SNP) | VAF 17/266 reads (6%) | called by muse, mutect2
- ZFR2 | c.2706G>T p.P902= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as rs199700045; called by muse, mutect2
- ZNF514 | c.777C>G p.P259= | Silent (SNP) | VAF 20/238 reads (8%) | catalogued as COSV99728048; called by muse, mutect2
- ZNF737 | c.633C>T p.N211= | Silent (SNP) | VAF 23/249 reads (9%) | catalogued as rs554872345, COSV101417590; called by muse, mutect2
- ZNF774 | c.579C>T p.D193= | Silent (SNP) | VAF 15/147 reads (10%) | called by muse, mutect2, varscan2
- AC068643.2 | n.593+274G>T | Intron (SNP) | VAF 10/90 reads (11%) | called by muse, mutect2, varscan2
- AC244517.10 | c.36-8892C>A | Intron (SNP) | VAF 45/451 reads (10%) | catalogued as COSV73144991; called by muse, mutect2, varscan2
- ACBD5 | chr10:27242101 G>T | 5'Flank (SNP) | VAF 13/77 reads (17%) | called by muse, mutect2, varscan2
- ACTB | c.-27-155C>T | Intron (SNP) | VAF 41/183 reads (22%) | called by muse, mutect2, varscan2
- AL590617.2 | n.1671G>C | RNA (SNP) | VAF 12/118 reads (10%) | called by muse, mutect2, varscan2
- ANKRD19P | n.94G>T | RNA (SNP) | VAF 19/181 reads (10%) | called by muse, mutect2
- ASCC1 | c.*765T>C | 3'UTR (SNP) | VAF 11/173 reads (6%) | catalogued as rs1456908388; called by muse, mutect2
- BMERB1 | c.230+17569C>A | Intron (SNP) | VAF 10/150 reads (7%) | called by muse, mutect2
- C6orf89 | chr6:36923557 C>T | 3'Flank (SNP) | VAF 16/122 reads (13%) | called by muse, mutect2, varscan2
- CADPS | c.1325+19185C>A | Intron (SNP) | VAF 8/168 reads (5%) | called by muse, mutect2
- CAPN2 | c.-78C>G | 5'UTR (SNP) | VAF 8/40 reads (20%) | called by muse, mutect2, varscan2
- CCDC162P | n.2252C>A | RNA (SNP) | VAF 29/296 reads (10%) | called by muse, mutect2
- CCDC33 | c.1938+382C>A | Intron (SNP) | VAF 48/244 reads (20%) | called by muse, varscan2
- CHRM2 | c.-47+33732G>T | Intron (SNP) | VAF 26/475 reads (5%) | called by muse, mutect2
- CHRNA4 | c.*130G>T | 3'UTR (SNP) | VAF 30/580 reads (5%) | called by muse, mutect2
- COL1A1 | c.1767+15A>T | Intron (SNP) | VAF 35/395 reads (9%) | called by muse, mutect2
- COL22A1 | c.*62G>T | 3'UTR (SNP) | VAF 82/280 reads (29%) | called by muse, mutect2, varscan2
- COL5A1 | c.5136+42C>A | Intron (SNP) | VAF 39/332 reads (12%) | called by muse, mutect2, varscan2
- CTAGE11P | n.285C>T | RNA (SNP) | VAF 58/797 reads (7%) | called by muse, mutect2
- CYP11B2 | c.395+633G>T | Intron (SNP) | VAF 52/217 reads (24%) | catalogued as COSV59997888; called by muse, mutect2, varscan2
- DCDC1 | c.2715+8164G>C | Intron (SNP) | VAF 8/103 reads (8%) | catalogued as COSV60305064; called by muse, mutect2
- DCHS1 | c.*239C>T | 3'UTR (SNP) | VAF 6/38 reads (16%) | catalogued as rs1364750157; called by muse, mutect2, varscan2
- DEFB118 | c.-9C>G | 5'UTR (SNP) | VAF 25/241 reads (10%) | catalogued as COSV53619967; called by muse, mutect2, varscan2
- EPB41L1 | c.-1C>T | 5'UTR (SNP) | VAF 14/160 reads (9%) | called by muse, mutect2
- EPO | c.-6G>T | 5'UTR (SNP) | VAF 7/66 reads (11%) | called by muse, mutect2, varscan2
- ERAL1 | chr17:28861598 G>A | 3'Flank (SNP) | VAF 19/178 reads (11%) | called by muse, mutect2, varscan2
- EYA4 | c.1757-109C>A | Intron (SNP) | VAF 38/492 reads (8%) | called by muse, mutect2
- EYS | c.1767-6810C>T | Intron (SNP) | VAF 48/662 reads (7%) | called by muse, mutect2
- F2 | c.240+25G>A | Intron (SNP) | VAF 21/216 reads (10%) | called by muse, mutect2
- FAM172BP | n.393T>A | RNA (SNP) | VAF 17/175 reads (10%) | called by muse, mutect2
- FAM172BP | n.394G>T | RNA (SNP) | VAF 18/173 reads (10%) | called by muse, mutect2, varscan2
- FNDC8 | c.-23G>A | 5'UTR (SNP) | VAF 33/326 reads (10%) | catalogued as rs189808081, COSV99338887; called by muse, mutect2, varscan2
- FNTA | c.*45G>A | 3'UTR (SNP) | VAF 8/115 reads (7%) | called by muse, mutect2
- FOXRED1 | c.*109C>G | 3'UTR (SNP) | VAF 16/178 reads (9%) | catalogued as COSV99702911; called by muse, mutect2
- GABRB1 | c.240+131C>A | Intron (SNP) | VAF 12/140 reads (9%) | called by muse, mutect2
- GABRB3 | c.241-20979C>T | Intron (SNP) | VAF 50/225 reads (22%) | called by muse, mutect2, varscan2
59 further variants in this file (0 protein-altering or splice-affecting, 0 silent, 59 other) are not listed here.
